Somatic mutation profile of tumor specimen C3L-09223-01 (aliquot CPT0487080006) from CPTAC case C3L-09223, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 81.2 years (29,650 days).
Specimen C3L-09223-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Head & Neck; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e239483b-6acf-4c48-bac1-a02ee25b336e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-09223-31 (Blood Derived Normal), aliquot CPT0487110002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/215284f9-a6d8-40fb-b0ce-fe4a2dc17ed8

The open-access MAF lists 2,412 somatic variants for this specimen: 1,553 protein-altering or splice-affecting, 771 silent, 88 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,438, Silent 771, Nonsense Mutation 74, Intron 49, Splice Region 15, Splice Site 12, 3'UTR 11, 5'Flank 9, 3'Flank 7, 5'UTR 7, RNA 5, Frame Shift Del 4.

Variants (750 of 2,412; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNMT3A | c.1903C>T p.R635W | Missense Mutation (SNP) | VAF 163/413 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs144689354, CM137477, COSV53038925; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- EDAR | c.292C>T p.R98W | Missense Mutation (SNP) | VAF 217/534 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs557166582, CM122441, COSV51502231; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- F13A1 | c.514C>T p.R172* | Nonsense Mutation (SNP) | VAF 422/695 reads (61%) | catalogued as rs121913065, CM930201, COSV53553799, COSV53554927; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FAM83H | c.2029C>T p.Q677* | Nonsense Mutation (SNP) | VAF 257/881 reads (29%) | catalogued as rs137854440, CM087429; ClinVar: pathogenic; called by muse, mutect2, varscan2
- GRIN2A | c.2095C>T p.P699S | Missense Mutation (SNP) | VAF 189/487 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs1555491648, CM138230, COSV58019167, COSV58047483; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PEX13 | c.508C>T p.R170* | Nonsense Mutation (SNP) | VAF 138/313 reads (44%) | catalogued as rs553968959, COSV54369896, COSV99692656; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PHEX | c.1880G>A p.W627* | Nonsense Mutation (SNP) | VAF 89/252 reads (35%) | catalogued as rs1085307584; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SCN2A | c.2995G>A p.E999K | Missense Mutation (SNP) | VAF 165/448 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.85); catalogued as rs796053126, CM139611, COSV51835030; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN4A | c.4342C>T p.R1448C | Missense Mutation (SNP) | VAF 192/513 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121908544, CM941272, CM991125; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.590T>G p.V197G | Missense Mutation (SNP) | VAF 146/212 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM994748, COSV52661145, COSV52810143, COSV53120183; called by muse, mutect2, varscan2
- A1BG | c.1198C>T p.P400S | Missense Mutation (SNP) | VAF 134/318 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.323); catalogued as rs771372524; called by muse, varscan2
- A1CF | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 105/149 reads (70%) | catalogued as COSV50995615; called by muse, mutect2, varscan2
- A1CF | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 114/176 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.218); catalogued as COSV50957343, COSV51028098; called by muse, mutect2, varscan2
- ABAT | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 191/531 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV51621468; called by muse, mutect2, varscan2
- ABCA10 | c.536C>T p.S179F | Missense Mutation (SNP) | VAF 106/295 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52230900; called by muse, mutect2
- ABCA12 | c.2266G>A p.D756N (on ENST00000272895 / NM_173076.3; = p.D438N on NM_015657.3) | Missense Mutation (SNP) | VAF 144/370 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.24); catalogued as COSV55962511; called by muse, mutect2, varscan2
- ABO | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 168/403 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs374698850; called by muse, mutect2, varscan2
- ABRA | c.122G>A p.S41N | Missense Mutation (SNP) | VAF 221/579 reads (38%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV100357514; called by muse, mutect2
- AC073610.2 | c.517G>A p.E173K | Missense Mutation (SNP) | VAF 117/353 reads (33%) | SIFT tolerated, low confidence (0.69); catalogued as COSV57198206; called by muse, mutect2, varscan2
- AC244197.3 | c.481G>A p.E161K | Missense Mutation (SNP) | VAF 454/856 reads (53%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as COSV61713926; called by muse, mutect2, varscan2
- ACACB | c.812C>T p.A271V | Missense Mutation (SNP) | VAF 146/416 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749130358, COSV58134352; called by muse, mutect2
- ACADM | c.760G>A p.D254N | Missense Mutation (SNP) | VAF 196/646 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.092); catalogued as COSV57714280; called by muse, mutect2, varscan2
- ACE | c.1710G>A p.R570= | Splice Region (SNP) | VAF 99/287 reads (34%) | catalogued as rs1393920320; called by muse, mutect2, varscan2
- ACMSD | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 146/392 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598885, COSV51606002, COSV51609903; called by muse, mutect2, varscan2
- ACTG2 | c.562G>A p.D188N | Missense Mutation (SNP) | VAF 182/842 reads (22%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.142); catalogued as COSV100609180; called by muse, mutect2, varscan2
- ADAM19 | c.509C>T p.P170L | Missense Mutation (SNP) | VAF 195/290 reads (67%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.942); catalogued as rs374662706; called by muse, mutect2, varscan2
- ADAM19 | c.508C>T p.P170S | Missense Mutation (SNP) | VAF 195/291 reads (67%) | SIFT tolerated (0.27); PolyPhen benign (0.386); catalogued as rs377731134; called by muse, mutect2, varscan2
- ADAM32 | c.814G>A p.D272N | Missense Mutation (SNP) | VAF 103/242 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV101165420; called by muse, mutect2, varscan2
- ADAM7 | c.1181C>T p.P394L | Missense Mutation (SNP) | VAF 173/486 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs775928329; called by muse, mutect2, varscan2
- ADAMTS5 | c.268C>T p.L90F | Missense Mutation (SNP) | VAF 284/739 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.067); catalogued as rs778906997; called by muse, mutect2
- ADGRF3 | c.818G>A p.G273E | Missense Mutation (SNP) | VAF 162/402 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs1335834654; called by muse, varscan2
- ADGRG4 | c.5303C>T p.S1768F | Missense Mutation (SNP) | VAF 349/701 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as COSV54959950; called by muse, mutect2, varscan2
- ADGRG4 | c.8261C>T p.S2754F | Missense Mutation (SNP) | VAF 158/578 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1296863852; called by muse, mutect2, varscan2
- ADGRV1 | c.14837G>A p.G4946E | Missense Mutation (SNP) | VAF 101/242 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV67979614; called by muse, mutect2, varscan2
- ADRA2B | c.833C>T p.P278L | Missense Mutation (SNP) | VAF 424/778 reads (54%) | SIFT deleterious (0.03); PolyPhen benign (0.143); catalogued as COSV69788312; called by muse, varscan2
- AGBL1 | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 184/493 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0.169); catalogued as COSV101222723; called by muse, mutect2, varscan2
- AGO2 | c.2252G>C p.C751S | Missense Mutation (SNP) | VAF 136/531 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV55050841; called by muse, mutect2, varscan2
- AKAP4 | c.745C>T p.H249Y | Missense Mutation (SNP) | VAF 235/572 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.576); catalogued as rs782799515; called by muse, mutect2, varscan2
- AKR1D1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 133/357 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.463); catalogued as COSV54336211; called by muse, mutect2, varscan2
- ALDH5A1 | c.1493C>T p.S498F | Missense Mutation (SNP) | VAF 191/717 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as rs867032162, COSV62372820; called by muse, mutect2, varscan2
- ALMS1 | c.8848C>T p.P2950S | Missense Mutation (SNP) | VAF 182/775 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV52524750; called by muse, mutect2, varscan2
- ALPK3 | c.655G>T p.D219Y | Missense Mutation (SNP) | VAF 194/477 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs148244525; called by muse, mutect2, varscan2
- AMDHD1 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 169/442 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.007); catalogued as rs1298421013; called by muse, mutect2, varscan2
- AMY2A | c.232C>G p.Q78E | Missense Mutation (SNP) | VAF 285/986 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101340658; called by muse, mutect2, varscan2
- AMY2A | c.1138G>A p.G380R | Missense Mutation (SNP) | VAF 195/1107 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.738); catalogued as rs1347919127; called by muse, mutect2, varscan2
- ANAPC2 | c.1891G>A p.A631T | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); catalogued as rs550478759; called by muse, mutect2, varscan2
- ANK1 | c.4795G>A p.E1599K | Missense Mutation (SNP) | VAF 183/448 reads (41%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.036); catalogued as rs896900492, COSV55876007; called by muse, mutect2, varscan2
- ANK2 | c.6460C>T p.R2154C | Missense Mutation (SNP) | VAF 84/363 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); catalogued as rs767226942; called by muse, mutect2, varscan2
- ANK3 | c.12487C>T p.R4163* (on ENST00000280772 / NM_001320874.2; = p.R684* on NM_001149.3) | Nonsense Mutation (SNP) | VAF 103/156 reads (66%) | catalogued as COSV55058581; called by muse, mutect2, varscan2
- ANKRD30A | c.3328G>A p.E1110K (on ENST00000611781; = p.E1054K on NM_052997.2) | Missense Mutation (SNP) | VAF 91/119 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs267602485, COSV64603763; called by muse, mutect2, varscan2
- ANKRD30A | c.4102G>A p.E1368K (on ENST00000611781; = p.E1312K on NM_052997.2) | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.102); catalogued as COSV64609832; called by muse, mutect2, varscan2
- ANKS1A | c.3029C>T p.S1010F | Missense Mutation (SNP) | VAF 126/528 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64464301; called by muse, mutect2, varscan2
- ANKUB1 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 134/186 reads (72%) | SIFT tolerated (0.05); PolyPhen benign (0.101); catalogued as COSV67167302; called by muse, mutect2, varscan2
- ANO4 | c.1274G>A p.G425E (on ENST00000392977 / NM_001286615.2; = p.G390E on NM_178826.4) | Missense Mutation (SNP) | VAF 152/394 reads (39%) | SIFT tolerated (0.39); PolyPhen benign (0.17); catalogued as COSV100153491; called by muse, mutect2, varscan2
- ANO4 | c.2303G>A p.G768E (on ENST00000392977 / NM_001286615.2; = p.G733E on NM_178826.4) | Missense Mutation (SNP) | VAF 92/198 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54585945; called by muse, mutect2, varscan2
- ANXA7 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 134/200 reads (67%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs867363009, COSV100873495; called by muse, mutect2, varscan2
- AOC1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 268/643 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.48); catalogued as rs895379019; called by muse, mutect2, varscan2
- APOB | c.7423G>A p.A2475T | Missense Mutation (SNP) | VAF 169/411 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.006); catalogued as COSV51923632; called by muse, mutect2, varscan2
- APOE | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 137/332 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV99376218; called by muse, mutect2, varscan2
- AQP7 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 142/381 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.102); catalogued as rs145775825; called by muse, mutect2, varscan2
- ARHGEF12 | c.4415C>T p.P1472L | Missense Mutation (SNP) | VAF 160/245 reads (65%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.157); catalogued as COSV63103172; called by muse, mutect2, varscan2
- ARMH2 | c.229C>T p.Q77* | Nonsense Mutation (SNP) | VAF 269/522 reads (52%) | catalogued as rs773974934; called by muse, mutect2, varscan2
- ART4 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 142/396 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs1201103453; called by muse, mutect2, varscan2
- ASB17 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 195/607 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.981); catalogued as rs1389873604, COSV99407755, COSV99407871, COSV99407958; called by muse, mutect2, varscan2
- ASTN1 | c.3631G>A p.D1211N | Missense Mutation (SNP) | VAF 125/181 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62504448; called by muse, mutect2, varscan2
- ATAD2B | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 74/248 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.31); catalogued as rs1416775351; called by muse, mutect2, varscan2
- ATAT1 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 227/502 reads (45%) | SIFT tolerated (0.44); PolyPhen benign (0.386); catalogued as rs1425184967; called by mutect2, varscan2
- ATCAY | c.75C>T p.P25= | Splice Region (SNP) | VAF 140/336 reads (42%) | catalogued as rs1444600952; called by muse, mutect2, varscan2
- ATCAY | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 228/600 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs375699107; called by muse, mutect2, varscan2
- ATP12A | c.637C>T p.Q213* | Nonsense Mutation (SNP) | VAF 189/491 reads (38%) | catalogued as COSV54523730; called by muse, mutect2, varscan2
- ATP1A3 | c.1810G>A p.D604N (on ENST00000545399 / NM_001256214.2; = p.D591N on NM_152296.5) | Missense Mutation (SNP) | VAF 154/410 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV100131950; called by muse, mutect2, varscan2
- ATP1B4 | c.1027G>A p.D343N (on ENST00000218008 / NM_001142447.3; = p.D339N on NM_012069.5) | Missense Mutation (SNP) | VAF 222/530 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54314478, COSV99486544; called by muse, mutect2, varscan2
- ATP6V1E2 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 124/314 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.26); catalogued as rs370738793; called by muse, mutect2, varscan2
- ATRX | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 213/499 reads (43%) | catalogued as rs1311466929, COSV64873935; called by muse, mutect2, varscan2
- B4GALNT2 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 155/385 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs780338935, COSV55928398; called by muse, mutect2, varscan2
- BAAT | c.982G>A p.D328N | Missense Mutation (SNP) | VAF 197/591 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52291427; called by muse, mutect2, varscan2
- BCAN | c.166C>T p.P56S | Missense Mutation (SNP) | VAF 1017/1414 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100227975; called by muse, mutect2, varscan2
- BCL11A | c.1190C>T p.S397L (on ENST00000335712 / NM_001365609.1; = p.S431L on NM_018014.4) | Missense Mutation (SNP) | VAF 164/488 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as rs138166869, COSV59625097; called by muse, mutect2, varscan2
- BCLAF3 | c.1205C>T p.S402L | Missense Mutation (SNP) | VAF 155/419 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs1203469952; called by muse, mutect2, varscan2
- BCOR | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 175/488 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV60698999; called by muse, mutect2, varscan2
- BCORL1 | c.4765G>A p.D1589N | Missense Mutation (SNP) | VAF 361/738 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0.117); catalogued as rs150455678, COSV99501232; called by muse, mutect2, varscan2
- BIN1 | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 115/270 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs532260569; called by muse, mutect2, varscan2
- BMP10 | c.172A>G p.M58V | Missense Mutation (SNP) | VAF 181/415 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs751233610; called by muse, mutect2, varscan2
- BRCA2 | c.6215C>T p.S2072F | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.431); catalogued as rs80358862, CM023885, COSV66459508; called by muse, mutect2, varscan2
- BRINP1 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 177/478 reads (37%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.037); catalogued as COSV56303837, COSV56317776; called by muse, mutect2, varscan2
- BSN | c.3257G>A p.R1086K | Missense Mutation (SNP) | VAF 214/587 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1401358675; called by muse, mutect2, varscan2
- BSN | c.9179C>T p.A3060V | Missense Mutation (SNP) | VAF 277/649 reads (43%) | SIFT tolerated (0.44); PolyPhen benign (0.014); catalogued as COSV56516195; called by muse, mutect2, varscan2
- C12orf42 | c.307C>T p.H103Y | Missense Mutation (SNP) | VAF 124/357 reads (35%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs1354629031, COSV59382911; called by muse, mutect2, varscan2
- C1orf127 | c.1226G>A p.G409E | Missense Mutation (SNP) | VAF 228/851 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs765408636; called by muse, mutect2, varscan2
- C2CD4D | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 281/1351 reads (21%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as rs938762232; called by muse, mutect2, varscan2
- C2orf66 | c.187C>T p.P63S | Missense Mutation (SNP) | VAF 167/456 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs868252979; called by muse, mutect2, varscan2
- C3 | c.3761G>A p.R1254H | Missense Mutation (SNP) | VAF 161/410 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.801); catalogued as rs571907143, COSV55569378; called by muse, mutect2, varscan2
- C4orf50 | c.700C>T p.Q234* (on ENST00000324058; = p.Q1466* on NM_001364689.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 151/378 reads (40%) | catalogued as COSV60688647; called by muse, mutect2, varscan2
- C5AR2 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 200/581 reads (34%) | SIFT tolerated (0.57); PolyPhen benign (0.39); catalogued as COSV99953763; called by muse, mutect2, varscan2
- C5orf38 | c.395C>A p.A132E | Missense Mutation (SNP) | VAF 150/394 reads (38%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.036); catalogued as rs767920768; called by muse, mutect2, varscan2
- C7 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 162/616 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57472311; called by muse, mutect2, varscan2
- C8orf58 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 212/514 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs1239796514; called by muse, mutect2, varscan2
- CACNA1B | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 91/626 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs1182464278; called by muse, mutect2, varscan2
- CACNA1C | c.6464G>A p.G2155E (on ENST00000399634 / NM_001167625.1; = p.G2084E on NM_000719.7) | Missense Mutation (SNP) | VAF 209/558 reads (37%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.306); catalogued as rs1381771539; called by muse, mutect2, varscan2
- CACNA1E | c.6478C>T p.P2160S (on ENST00000367573 / NM_001205293.3; = p.P2117S on NM_000721.4) | Missense Mutation (SNP) | VAF 240/330 reads (73%) | SIFT deleterious (0.04); PolyPhen benign (0.091); catalogued as COSV62403669; called by muse, mutect2, varscan2
- CACNA1I | c.1588C>T p.P530S | Missense Mutation (SNP) | VAF 156/384 reads (41%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1365406479; called by muse, mutect2, varscan2
- CACNG7 | c.587C>A p.S196Y | Missense Mutation (SNP) | VAF 145/358 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55813042; called by muse, mutect2, varscan2
- CAD | c.5209C>T p.R1737W | Missense Mutation (SNP) | VAF 196/484 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.765); catalogued as rs763355511; called by muse, mutect2
- CALB2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 79/230 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as COSV100226461, COSV56940629; called by muse, mutect2, varscan2
- CALHM4 | c.482C>T p.P161L (on ENST00000368596 / NM_001366078.1; = p.P18L on NM_001256887.3) | Missense Mutation (SNP) | VAF 189/260 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1413932713; called by muse, mutect2, varscan2
- CAMTA1 | c.2009C>T p.S670F | Missense Mutation (SNP) | VAF 243/587 reads (41%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.365); catalogued as COSV100351407; called by muse, mutect2, varscan2
- CAPN6 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 240/626 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs777349721; called by muse, mutect2, varscan2
- CAPZA3 | c.635G>A p.S212N | Missense Mutation (SNP) | VAF 186/469 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.783); catalogued as COSV56850026; called by muse, mutect2, varscan2
- CATSPERB | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 327/583 reads (56%) | SIFT tolerated (0.38); PolyPhen benign (0.009); catalogued as COSV56429523; called by muse, mutect2, varscan2
- CATSPERG | c.1811G>A p.R604K | Missense Mutation (SNP) | VAF 97/301 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1000937974; called by muse, mutect2, varscan2
- CCDC116 | c.1159C>T p.P387S | Missense Mutation (SNP) | VAF 225/566 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as rs1356623525, COSV53042376; called by muse, mutect2, varscan2
- CCDC116 | c.1160C>T p.P387L | Missense Mutation (SNP) | VAF 224/564 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.408); catalogued as COSV99489316; called by muse, mutect2, varscan2
- CCDC141 | c.3791C>T p.S1264F | Missense Mutation (SNP) | VAF 115/304 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as rs767025406; called by muse, mutect2, varscan2
- CCDC141 | c.1882C>T p.L628F | Missense Mutation (SNP) | VAF 159/397 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV55375917; called by muse, mutect2, varscan2
- CCDC174 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 104/290 reads (36%) | SIFT tolerated (0.32); PolyPhen benign (0.296); catalogued as rs866411473, COSV53783586; called by muse, mutect2
- CCDC180 | c.4700G>A p.G1567E | Missense Mutation (SNP) | VAF 115/311 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63833459; called by muse, mutect2, varscan2
- CCDC190 | c.312G>A p.M104I | Missense Mutation (SNP) | VAF 107/547 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV63362644; called by muse, mutect2, varscan2
- CCDC27 | c.1139G>A p.R380K | Missense Mutation (SNP) | VAF 256/629 reads (41%) | SIFT tolerated (0.83); PolyPhen benign (0.001); catalogued as COSV53901160; called by muse, mutect2, varscan2
- CCDC66 | c.711-1G>A p.X237_splice (on ENST00000394672 / NM_001353147.1; = p.X203_splice on NM_001012506.5 and 6 other RefSeq transcripts) | Splice Site (SNP) | VAF 97/265 reads (37%) | catalogued as rs755251110; called by muse, mutect2, varscan2
- CCM2L | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 249/570 reads (44%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.923); catalogued as rs149172226, COSV52950193; called by muse, mutect2, varscan2
- CD1A | c.328C>T p.P110S | Missense Mutation (SNP) | VAF 98/591 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as rs752354521, COSV56860895; called by muse, mutect2, varscan2
- CD207 | c.695C>T p.S232L | Missense Mutation (SNP) | VAF 198/450 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781970590, COSV69651949; called by muse, mutect2
- CD300A | c.98G>A p.S33N | Missense Mutation (SNP) | VAF 139/381 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.646); catalogued as rs1362879418; called by muse, mutect2, varscan2
- CD5L | c.661G>A p.G221R | Missense Mutation (SNP) | VAF 160/890 reads (18%) | SIFT tolerated (0.59); PolyPhen benign (0.01); catalogued as COSV63821986; called by muse, mutect2, varscan2
- CDH4 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 236/824 reads (29%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.997); catalogued as rs1228837257; called by muse, mutect2, varscan2
- CDH5 | c.2084C>T p.A695V | Missense Mutation (SNP) | VAF 287/614 reads (47%) | SIFT tolerated (0.32); PolyPhen benign (0.01); catalogued as rs768164275, COSV58516079; called by muse, varscan2
- CDKL5 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 148/375 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.018); catalogued as CM112372; called by muse, varscan2
- CELSR1 | c.5749G>A p.E1917K | Missense Mutation (SNP) | VAF 167/494 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as rs759648050, COSV53082712; called by muse, mutect2, varscan2
- CEP295 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 66/88 reads (75%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as rs1181907086; called by muse, mutect2, varscan2
- CFAP46 | c.2041C>T p.P681S | Missense Mutation (SNP) | VAF 175/283 reads (62%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs747107998, COSV63951231; called by muse, mutect2, varscan2
- CFAP52 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 156/241 reads (65%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as rs201352201; called by muse, mutect2, varscan2
- CFAP54 | c.7588C>T p.R2530C | Missense Mutation (SNP) | VAF 87/246 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV61573171; called by muse, mutect2, varscan2
- CFAP61 | c.2827G>A p.D943N | Missense Mutation (SNP) | VAF 72/215 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV55617748; called by muse, mutect2, varscan2
- CFHR5 | c.676G>A p.E226K | Missense Mutation (SNP) | VAF 149/217 reads (69%) | SIFT tolerated (0.23); PolyPhen benign (0.259); catalogued as COSV56821997; called by muse, mutect2, varscan2
- CHD7 | c.8594C>T p.S2865L | Missense Mutation (SNP) | VAF 507/866 reads (59%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as rs147534616; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- CHGB | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 187/509 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV66759717; called by muse, mutect2, varscan2
- CHIA | c.592C>T p.P198S (on ENST00000343320; = p.P90S on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 203/372 reads (55%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.893); catalogued as COSV58478108; called by muse, mutect2, varscan2
- CHL1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1159504136, COSV56587630; called by muse, mutect2, varscan2
- CHPF | c.1478G>A p.R493H | Missense Mutation (SNP) | VAF 204/497 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as rs779983221, COSV60534497; called by muse, mutect2, varscan2
- CHRDL2 | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 134/881 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.437); catalogued as COSV55225208; called by muse, mutect2, varscan2
- CHRM3 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 165/232 reads (71%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as COSV55101421; called by muse, mutect2, varscan2
- CHRNB3 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 176/521 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99251381; called by muse, mutect2, varscan2
- CHST4 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 175/473 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV58296522; called by muse, mutect2, varscan2
- CILP2 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 152/420 reads (36%) | catalogued as rs754649866, COSV52279833; called by muse, mutect2, varscan2
- CLASP2 | c.3679C>T p.H1227Y (on ENST00000359576; = p.H1226Y on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 144/356 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.102); catalogued as rs928560904; called by muse, mutect2, varscan2
- CLCNKA | c.827C>T p.P276L | Missense Mutation (SNP) | VAF 117/698 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100509819; called by muse, varscan2
- CLEC18A | c.1261G>A p.D421N | Missense Mutation (SNP) | VAF 66/404 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.996); catalogued as rs201545424; called by muse, mutect2, varscan2
- CLEC3A | c.476C>T p.S159F (on ENST00000651443; = p.S150F on NM_005752.6) | Missense Mutation (SNP) | VAF 203/528 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.567); catalogued as COSV55220997; called by muse, mutect2, varscan2
- CLEC6A | c.593G>A p.R198K | Missense Mutation (SNP) | VAF 154/373 reads (41%) | SIFT tolerated (0.33); PolyPhen benign (0.066); catalogued as COSV65987964; called by muse, mutect2, varscan2
- CLEC7A | c.494G>A p.G165E (on ENST00000304084 / NM_197947.3; = p.G119E on NM_022570.5) | Missense Mutation (SNP) | VAF 90/209 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1474426560; called by muse, mutect2, varscan2
- CLNK | c.896C>T p.S299F | Missense Mutation (SNP) | VAF 126/312 reads (40%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs762619599; called by muse, mutect2, varscan2
- CLPTM1 | c.1321C>T p.R441W | Missense Mutation (SNP) | VAF 115/304 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs752663268, COSV61612413; called by muse, mutect2, varscan2
- CLTCL1 | c.4745T>G p.V1582G (on ENST00000427926 / NM_007098.4; = p.V1525G on NM_001835.4) | Missense Mutation (SNP) | VAF 184/434 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.24); catalogued as COSV53206519; called by muse, mutect2, varscan2
- CNBD1 | c.910G>A p.E304K | Missense Mutation (SNP) | VAF 59/225 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1190645586, COSV73074002; called by muse, mutect2, varscan2
- CNTN5 | c.1852G>A p.E618K | Missense Mutation (SNP) | VAF 163/235 reads (69%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99679151; called by muse, mutect2, varscan2
- CNTNAP2 | c.2096C>T p.P699L | Missense Mutation (SNP) | VAF 88/241 reads (37%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.803); catalogued as COSV100673551; called by muse, mutect2, varscan2
- COG7 | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 167/465 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.837); catalogued as COSV56152096; called by muse, mutect2, varscan2
- COL15A1 | c.1358C>A p.P453Q | Missense Mutation (SNP) | VAF 93/271 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV66643185; called by muse, mutect2, varscan2
- COL18A1 | c.3937C>T p.P1313S (on ENST00000359759 / NM_130444.3; = p.P1078S on NM_030582.4) | Missense Mutation (SNP) | VAF 164/427 reads (38%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as rs762255278; called by muse, mutect2, varscan2
- COL1A2 | c.2347C>T p.P783S | Missense Mutation (SNP) | VAF 156/395 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs372702749; called by muse, mutect2, varscan2
- COL21A1 | c.1481G>A p.G494E | Missense Mutation (SNP) | VAF 102/287 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99777264; called by muse, mutect2, varscan2
- COL22A1 | c.4777C>T p.P1593S | Missense Mutation (SNP) | VAF 223/842 reads (26%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.6); catalogued as COSV57328014; called by muse, mutect2, varscan2
- COL4A1 | c.3412C>T p.P1138S | Missense Mutation (SNP) | VAF 115/285 reads (40%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.971); catalogued as COSV65427363; called by muse, mutect2, varscan2
- COL4A4 | c.2399C>T p.P800L | Missense Mutation (SNP) | VAF 102/305 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.734); catalogued as rs200714000, COSV61632466; called by muse, mutect2, varscan2
- COL7A1 | c.5956G>A p.E1986K | Missense Mutation (SNP) | VAF 217/525 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.829); catalogued as rs144208360; called by muse, mutect2, varscan2
- COL7A1 | c.5856+1G>A p.X1952_splice | Splice Site (SNP) | VAF 149/395 reads (38%) | catalogued as CS120669, CS167149; called by muse, mutect2, varscan2
- CORIN | c.2594A>G p.H865R | Missense Mutation (SNP) | VAF 207/518 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs1336754351; called by muse, mutect2, varscan2
- CPA4 | c.646G>A p.D216N | Missense Mutation (SNP) | VAF 147/396 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55984132, COSV55985226; called by muse, mutect2, varscan2
- CPEB1 | c.1741C>T p.Q581* (on ENST00000617958; = p.Q516* on NM_030594.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 179/598 reads (30%) | catalogued as COSV55621913; called by muse, mutect2
- CPO | c.599A>G p.Q200R | Missense Mutation (SNP) | VAF 126/378 reads (33%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as COSV55939369; called by muse, mutect2, varscan2
- CPT1A | c.1201C>T p.R401C | Missense Mutation (SNP) | VAF 164/817 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.697); catalogued as rs754110528; called by muse, mutect2, varscan2
- CRACR2A | c.1606G>A p.E536K | Missense Mutation (SNP) | VAF 110/307 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.111); catalogued as COSV61543472; called by muse, mutect2, varscan2
- CREB5 | c.178C>T p.P60S (on ENST00000357727 / NM_182898.4; = p.P53S on NM_004904.3) | Missense Mutation (SNP) | VAF 127/192 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63220215; called by muse, mutect2, varscan2
- CREBBP | c.2684C>G p.S895C | Missense Mutation (SNP) | VAF 216/590 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.628); catalogued as COSV52123513; called by muse, mutect2, varscan2
- CRISP1 | c.452C>T p.S151F | Missense Mutation (SNP) | VAF 156/639 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59995224; called by muse, mutect2, varscan2
- CRYGC | c.229C>T p.R77C | Missense Mutation (SNP) | VAF 111/352 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.68); catalogued as rs746609116, COSV52204729; called by muse, mutect2, varscan2
- CSMD1 | c.8492G>A p.G2831E (on ENST00000520002; = p.G2830E on NM_033225.6) | Missense Mutation (SNP) | VAF 164/447 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59285758; called by muse, mutect2, varscan2
- CSMD3 | c.5843G>A p.G1948E (on ENST00000297405 / NM_001363185.1; = p.G1844E on NM_052900.3) | Missense Mutation (SNP) | VAF 142/374 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52323142; called by muse, mutect2, varscan2
- CTAGE1 | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 99/254 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs1460375878; called by muse, mutect2, varscan2
- CTAGE4 | c.2212C>T p.P738S | Missense Mutation (SNP) | VAF 142/562 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.31); catalogued as rs1251030175; called by muse, varscan2
- CTNND1 | c.604C>T p.L202F | Missense Mutation (SNP) | VAF 206/579 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.676); catalogued as rs1273581564; called by muse, mutect2, varscan2
- CUX2 | c.2605C>T p.P869S | Missense Mutation (SNP) | VAF 258/609 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV55646583; called by muse, mutect2, varscan2
- CWH43 | c.1354C>T p.H452Y | Missense Mutation (SNP) | VAF 103/288 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs149402114, COSV56945000; called by muse, mutect2, varscan2
- CYP21A2 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 115/688 reads (17%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.738); catalogued as rs528524868, COSV64478396; called by muse, mutect2, varscan2
- CYP2C19 | c.748G>A p.E250K | Missense Mutation (SNP) | VAF 118/197 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.346); catalogued as rs866704734, COSV64907162; called by muse, mutect2, varscan2
- CYP2E1 | c.638C>T p.P213L | Missense Mutation (SNP) | VAF 80/121 reads (66%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.825); catalogued as COSV53314621; called by muse, mutect2, varscan2
- CYP2F1 | c.122G>A p.G41E | Missense Mutation (SNP) | VAF 206/485 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406970357, COSV100462465; called by muse, mutect2
- CYP4F12 | c.729G>A p.M243I | Missense Mutation (SNP) | VAF 159/423 reads (38%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs550293120; called by muse, mutect2, varscan2
- CYP4V2 | c.1181C>T p.S394F | Missense Mutation (SNP) | VAF 150/229 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs762287609, COSV101114946; called by muse, mutect2, varscan2
- CYP4X1 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 169/419 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.261); catalogued as rs377650246; called by muse, mutect2, varscan2
- CYP4Z1 | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 103/271 reads (38%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.965); catalogued as rs1206792114, COSV61964908; called by muse, mutect2, varscan2
- CYRIA | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 129/333 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV62865079; called by muse, mutect2, varscan2
- CYSLTR1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 113/326 reads (35%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as COSV64820655; called by muse, mutect2, varscan2
- DCAF1 | c.1508C>T p.A503V | Missense Mutation (SNP) | VAF 149/392 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.197); catalogued as rs1553634991; called by muse, mutect2, varscan2
- DCHS2 | c.1541C>T p.A514V | Missense Mutation (SNP) | VAF 210/312 reads (67%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.699); catalogued as rs1011388540, COSV59734454; called by muse, mutect2, varscan2
- DCN | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 97/308 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV50008499; called by muse, mutect2, varscan2
- DCN | c.238C>T p.P80S | Missense Mutation (SNP) | VAF 103/338 reads (30%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.861); catalogued as COSV50006331; called by muse, mutect2, varscan2
- DCPS | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 99/142 reads (70%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.709); catalogued as rs935312176; called by muse, mutect2, varscan2
- DDHD1 | c.1963C>T p.L655F (on ENST00000323669; = p.L852F on NM_030637.3) | Missense Mutation (SNP) | VAF 126/354 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV60357397; called by mutect2, varscan2
- DDI1 | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 264/1133 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.154); catalogued as COSV56384469; called by muse, mutect2, varscan2
- DDX43 | c.1760C>T p.S587F | Missense Mutation (SNP) | VAF 152/386 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1394324671; called by muse, mutect2, varscan2
- DEFB1 | c.73C>T p.L25F | Missense Mutation (SNP) | VAF 96/262 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs542627909, COSV52412979; called by muse, mutect2, varscan2
- DEFB105A | c.95C>T p.S32F | Missense Mutation (SNP) | VAF 67/490 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.189); catalogued as COSV58294716; called by muse, mutect2, varscan2
- DENND5A | c.2101C>T p.R701W | Missense Mutation (SNP) | VAF 99/286 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.959); catalogued as rs758183835, COSV60233221, COSV60234125; called by muse, mutect2, varscan2
- DHX34 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 199/534 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1568395807, COSV60898204; called by muse, mutect2, varscan2
- DHX58 | c.773A>T p.Y258F | Missense Mutation (SNP) | VAF 141/439 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.332); catalogued as rs782514778; called by muse, mutect2, varscan2
- DIPK2B | c.613C>G p.R205G | Missense Mutation (SNP) | VAF 237/549 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV65005418; called by muse, mutect2, varscan2
- DMBT1 | c.5093G>A p.G1698E (on ENST00000338354 / NM_001377530.1; = p.G941E on NM_004406.3) | Missense Mutation (SNP) | VAF 312/712 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57560306; called by muse, mutect2, varscan2
- DNAH10 | c.6799G>A p.D2267N (on ENST00000409039; = p.D2206N on NM_207437.3) | Missense Mutation (SNP) | VAF 168/413 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101292410; called by muse, mutect2, varscan2
- DNAH10 | c.8887G>A p.E2963K (on ENST00000409039; = p.E2902K on NM_207437.3) | Missense Mutation (SNP) | VAF 254/653 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); catalogued as rs369042115; called by muse, mutect2
- DNAH5 | c.13117C>T p.P4373S | Missense Mutation (SNP) | VAF 125/334 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.14); catalogued as COSV54203644; called by muse, mutect2, varscan2
- DNAH5 | c.10658G>A p.R3553Q | Missense Mutation (SNP) | VAF 184/441 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.14); catalogued as rs144393366, COSV99448734; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DNAH5 | c.9275G>A p.G3092E | Missense Mutation (SNP) | VAF 355/443 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54209725, COSV54255649; called by muse, varscan2
- DNAH7 | c.5941G>A p.G1981R | Missense Mutation (SNP) | VAF 129/319 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56756454; called by muse, mutect2, varscan2
- DNAH7 | c.3697C>T p.R1233C | Missense Mutation (SNP) | VAF 202/450 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779775861, CM147034, COSV56786495; called by muse, mutect2, varscan2
- DPH2 | c.1354C>T p.L452F | Missense Mutation (SNP) | VAF 144/360 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs773272790; called by muse, mutect2, varscan2
- DPP10 | c.455C>T p.S152L | Missense Mutation (SNP) | VAF 54/192 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59686682; called by muse, mutect2, varscan2
- DPPA3 | c.322C>T p.R108C | Missense Mutation (SNP) | VAF 96/228 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.162); catalogued as rs1476085353, COSV61502941; called by muse, mutect2, varscan2
- DPYSL5 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 221/594 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs776793161, COSV56509191; called by muse, mutect2, varscan2
- DRP2 | c.1232G>A p.R411K | Missense Mutation (SNP) | VAF 164/410 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs868585753; called by muse, mutect2, varscan2
- DSC3 | c.443C>T p.S148F | Missense Mutation (SNP) | VAF 160/408 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs1413248107; called by muse, mutect2, varscan2
- DSCAM | c.781G>A p.D261N | Missense Mutation (SNP) | VAF 181/506 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs766601615, COSV68029034; called by muse, mutect2, varscan2
- DSEL | c.3640C>T p.R1214C | Missense Mutation (SNP) | VAF 124/191 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as rs776589023, COSV100025646; called by muse, mutect2, varscan2
- DSG2 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 186/469 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.028); catalogued as rs749602291, COSV55197247; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUSP22 | c.160C>T p.P54S | Missense Mutation (SNP) | VAF 87/611 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.003); catalogued as rs1452312293; called by muse, mutect2, varscan2
- EBF3 | c.1568C>T p.P523L | Missense Mutation (SNP) | VAF 106/178 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.012); catalogued as rs1404478635, COSV62480728; called by muse, mutect2, varscan2
- EDA | c.13G>A p.E5K | Missense Mutation (SNP) | VAF 179/441 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1427013678; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.979G>A p.G327R | Missense Mutation (SNP) | VAF 147/198 reads (74%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as rs1270644579; called by muse, mutect2, varscan2
- EFCAB8 | c.2821C>T p.P941S | Missense Mutation (SNP) | VAF 117/325 reads (36%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.95); catalogued as rs1354026107; called by muse, mutect2, varscan2
- EFHC2 | c.370G>A p.G124R | Missense Mutation (SNP) | VAF 99/268 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1248447801; called by muse, mutect2, varscan2
- EGFLAM | c.657G>A p.M219I | Missense Mutation (SNP) | VAF 197/622 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as rs369346695, COSV59296529; called by muse, varscan2
- ELF1 | c.903T>G p.D301E | Missense Mutation (SNP) | VAF 126/402 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.036); catalogued as COSV53497443; called by muse, mutect2, varscan2
- ELOA2 | c.284C>T p.S95F | Missense Mutation (SNP) | VAF 247/384 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV55297268; called by muse, mutect2, varscan2
- EMB | c.439G>A p.E147K | Missense Mutation (SNP) | VAF 87/257 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as COSV57480680; called by muse, mutect2, varscan2
- EMILIN3 | c.220G>A p.G74R | Missense Mutation (SNP) | VAF 142/366 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV60039189; called by muse, mutect2, varscan2
- ENPEP | c.274C>T p.R92* | Nonsense Mutation (SNP) | VAF 125/406 reads (31%) | catalogued as rs143343563, COSV54448047; called by muse, mutect2, varscan2
- ENPEP | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.987); catalogued as COSV54446739; called by muse, mutect2, varscan2
- ENTPD5 | c.1203C>T p.L401= | Splice Region (SNP) | VAF 108/463 reads (23%) | catalogued as rs145619742; called by muse, mutect2, varscan2
- EPB41L2 | c.1841C>T p.S614F | Missense Mutation (SNP) | VAF 88/133 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.649); catalogued as COSV61355938; called by muse, mutect2, varscan2
- EPB42 | c.947G>A p.G316E (on ENST00000441366 / NM_001114134.2; = p.G346E on NM_000119.3) | Missense Mutation (SNP) | VAF 114/155 reads (74%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.911); catalogued as rs751587323; called by muse, mutect2, varscan2
- ERBB4 | c.3866C>T p.S1289F | Missense Mutation (SNP) | VAF 133/358 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.28); catalogued as rs1365124530; called by muse, mutect2, varscan2
- ERVV-2 | c.832C>T p.P278S | Missense Mutation (SNP) | VAF 205/518 reads (40%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.9); catalogued as rs1288307074; called by mutect2, varscan2
- ETV7 | c.913G>A p.G305R | Missense Mutation (SNP) | VAF 231/392 reads (59%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.006); catalogued as COSV60318277; called by muse, mutect2, varscan2
- EXD3 | c.1636G>A p.E546K | Missense Mutation (SNP) | VAF 168/382 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.34); catalogued as rs750745784; called by muse, mutect2
- EYA1 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 255/456 reads (56%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.741); catalogued as rs866589605, COSV58160378; called by muse, mutect2, varscan2
- EZHIP | c.880G>A p.D294N | Missense Mutation (SNP) | VAF 294/772 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV100539791; called by muse, mutect2, varscan2
- F13B | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 136/214 reads (64%) | SIFT deleterious (0.03); PolyPhen benign (0.272); catalogued as COSV100803399; called by muse, mutect2, varscan2
- FAM135B | c.3193C>T p.P1065S | Missense Mutation (SNP) | VAF 190/775 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52709656, COSV52715574, COSV52746385; called by muse, mutect2, varscan2
- FAM13A | c.1931C>T p.S644F | Missense Mutation (SNP) | VAF 108/201 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs141057688, COSV51998667; called by muse, mutect2, varscan2
- FAM149B1 | c.1655G>A p.R552Q | Missense Mutation (SNP) | VAF 166/266 reads (62%) | SIFT tolerated (0.07); PolyPhen benign (0.065); catalogued as rs577915763; called by muse, mutect2, varscan2
- FAM205A | c.3889G>A p.D1297N | Missense Mutation (SNP) | VAF 204/494 reads (41%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as rs532422895, COSV66488667; called by muse, mutect2, varscan2
- FAM83H | c.967C>T p.P323S | Missense Mutation (SNP) | VAF 312/1031 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.814); catalogued as rs575327038; called by muse, mutect2, varscan2
- FAM9B | c.152C>T p.A51V | Missense Mutation (SNP) | VAF 121/336 reads (36%) | SIFT tolerated (1); PolyPhen possibly damaging (0.739); catalogued as rs752760601, COSV100511146; called by muse, mutect2, varscan2
- FARP1 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 204/435 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.122); catalogued as rs1296966653; called by muse, mutect2, varscan2
- FASTKD5 | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 187/503 reads (37%) | catalogued as rs757442015, COSV99417829; called by muse, mutect2, varscan2
- FAT4 | c.6607C>T p.R2203W | Missense Mutation (SNP) | VAF 84/378 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs374328795, COSV58685192; called by muse, mutect2
- FAT4 | c.12159G>A p.M4053I | Missense Mutation (SNP) | VAF 143/304 reads (47%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as rs868364718, COSV58696755; called by muse, mutect2, varscan2
- FAT4 | c.14819C>T p.P4940L | Missense Mutation (SNP) | VAF 79/339 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.994); catalogued as COSV100630440; called by muse, mutect2, varscan2
- FBLN5 | c.704G>A p.G235E | Missense Mutation (SNP) | VAF 98/446 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50903502; called by muse, mutect2, varscan2
- FBN3 | c.1873G>A p.E625K | Missense Mutation (SNP) | VAF 288/758 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs138440561; called by muse, mutect2
- FBXO24 | c.958G>A p.G320R (on ENST00000241071 / NM_033506.3; = p.G358R on NM_012172.5) | Missense Mutation (SNP) | VAF 119/299 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs946940461; called by muse, mutect2, varscan2
- FBXO34 | c.1109C>T p.S370F | Missense Mutation (SNP) | VAF 181/526 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1347291670; called by muse, mutect2, varscan2
- FBXO36 | c.140G>A p.R47Q | Missense Mutation (SNP) | VAF 129/327 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as rs201887524; called by muse, mutect2, varscan2
- FCAMR | c.1036G>A p.E346K | Missense Mutation (SNP) | VAF 216/335 reads (64%) | SIFT tolerated (0.41); PolyPhen benign (0.051); catalogued as rs894415166; called by muse, mutect2, varscan2
- FCN2 | c.476G>A p.W159* | Nonsense Mutation (SNP) | VAF 134/345 reads (39%) | catalogued as COSV99391369; called by muse, mutect2, varscan2
- FCN3 | c.463G>A p.G155R | Missense Mutation (SNP) | VAF 148/356 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99585437; called by muse, mutect2, varscan2
- FGD5 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 202/573 reads (35%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1342023684; called by muse, mutect2, varscan2
- FGD5 | c.817G>A p.E273K | Missense Mutation (SNP) | VAF 199/546 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.01); catalogued as rs758731769; called by muse, mutect2, varscan2
- FHAD1 | c.3248G>A p.R1083K | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.777); catalogued as COSV58990294; called by muse, mutect2, varscan2
- FILIP1 | c.2480C>T p.S827F | Missense Mutation (SNP) | VAF 144/395 reads (36%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV52733672; called by muse, mutect2, varscan2
- FLRT2 | c.1105C>T p.L369F | Missense Mutation (SNP) | VAF 362/633 reads (57%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as rs932839003; called by muse, mutect2, varscan2
- FNDC1 | c.2767G>A p.E923K | Missense Mutation (SNP) | VAF 233/329 reads (71%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.154); catalogued as rs764318394; called by muse, mutect2, varscan2
- FOXL1 | c.752C>T p.S251F | Missense Mutation (SNP) | VAF 225/358 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1464539433; called by muse, mutect2, varscan2
- FOXR2 | c.419C>T p.P140L | Missense Mutation (SNP) | VAF 285/616 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.001); catalogued as rs747403262, COSV59258259, COSV59258817; called by muse, mutect2, varscan2
- FPR1 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 109/304 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as rs1178403168, COSV100494163; called by muse, mutect2, varscan2
- FREM1 | c.3535C>T p.P1179S | Missense Mutation (SNP) | VAF 179/424 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1381393162; called by muse, mutect2, varscan2
- FSIP2 | c.1405G>A p.E469K | Missense Mutation (SNP) | VAF 133/335 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs911042698, COSV58081742; called by muse, mutect2, varscan2
- FSIP2 | c.14608G>A p.D4870N | Missense Mutation (SNP) | VAF 73/266 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.737); catalogued as COSV58087927; called by muse, mutect2, varscan2
- FUT6 | c.184C>T p.P62S | Missense Mutation (SNP) | VAF 219/573 reads (38%) | SIFT tolerated (0.89); PolyPhen benign (0.001); catalogued as rs1217355896, COSV54606643; called by muse, mutect2, varscan2
- GABRB2 | c.329G>A p.R110K | Missense Mutation (SNP) | VAF 192/287 reads (67%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.627); catalogued as COSV50929836; called by muse, mutect2, varscan2
- GABRG1 | c.634C>T p.P212S | Missense Mutation (SNP) | VAF 108/260 reads (42%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.861); catalogued as COSV99777487; called by muse, mutect2, varscan2
- GABRG1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 97/253 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs756710229, COSV54960181; called by muse, mutect2, varscan2
- GAL3ST1 | c.190C>T p.R64W | Missense Mutation (SNP) | VAF 236/550 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.553); catalogued as rs148732637; called by muse, varscan2
- GALNT15 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 170/532 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.021); catalogued as COSV100327802; called by muse, mutect2
- GATA5 | c.279C>G p.F93L | Missense Mutation (SNP) | VAF 281/1242 reads (23%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.846); catalogued as rs1555897010; called by muse, mutect2, varscan2
- GBA3 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 119/278 reads (43%) | SIFT tolerated (0.7); PolyPhen benign (0.02); catalogued as COSV72438158; called by muse, mutect2, varscan2
- GBP6 | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 197/321 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.235); catalogued as rs752593753, COSV65012630; called by muse, mutect2, varscan2
- GCOM1 | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 140/195 reads (72%) | SIFT tolerated (0.08); PolyPhen benign (0.099); catalogued as COSV51099608; called by muse, mutect2, varscan2
- GIMAP8 | c.776G>A p.G259E | Missense Mutation (SNP) | VAF 203/588 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1480798484, COSV56230984; called by muse, mutect2, varscan2
- GJD2 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 232/326 reads (71%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV99290951; called by muse, mutect2, varscan2
- GLDC | c.395C>T p.S132L | Missense Mutation (SNP) | VAF 211/497 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs386833576, CM061050, CM1510118, COSV58685120; called by muse, mutect2, varscan2
- GNAO1 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 177/423 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99341077; called by muse, mutect2, varscan2
- GNMT | c.541G>A p.D181N | Missense Mutation (SNP) | VAF 334/582 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs755100354, COSV55102134; called by muse, mutect2, varscan2
- GPAT4 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 160/397 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1300781541; called by muse, mutect2, varscan2
- GPAT4 | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 157/394 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs764802073; called by muse, mutect2, varscan2
- GPHN | c.1159C>T p.R387C (on ENST00000315266 / NM_001377519.1; = p.R420C on NM_020806.5) | Missense Mutation (SNP) | VAF 309/538 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59473880; called by muse, mutect2, varscan2
- GPR158 | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 198/272 reads (73%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV66277256; called by muse, mutect2, varscan2
- GPR55 | c.908G>A p.R303Q | Missense Mutation (SNP) | VAF 158/389 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs372743996; called by muse, mutect2, varscan2
- GRAMD1B | c.328C>T p.R110C | Missense Mutation (SNP) | VAF 171/237 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.946); catalogued as rs1203376594; called by muse, mutect2, varscan2
- GRB7 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 194/630 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as COSV100485669; called by muse, mutect2, varscan2
- GREB1L | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 109/344 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs569521616, COSV52560173; called by muse, mutect2, varscan2
- GRID2IP | c.3364C>T p.P1122S | Missense Mutation (SNP) | VAF 150/406 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as rs903298965; called by muse, mutect2, varscan2
- GRID2IP | c.102G>C p.K34N | Missense Mutation (SNP) | VAF 251/665 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs914349575; called by muse, mutect2, varscan2
- GRIK2 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 132/335 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100026847; called by muse, mutect2
- GRIK3 | c.394C>T p.H132Y | Missense Mutation (SNP) | VAF 217/558 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.764); catalogued as COSV66134854; called by muse, mutect2, varscan2
- GRM3 | c.1641G>A p.M547I | Missense Mutation (SNP) | VAF 201/512 reads (39%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs974856347, COSV64475525; called by muse, mutect2, varscan2
- GTF3C2 | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 118/338 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.37); catalogued as rs755964710, COSV99053802, COSV99272852; called by muse, mutect2
- HAPLN1 | c.523C>T p.H175Y | Missense Mutation (SNP) | VAF 158/420 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.012); catalogued as rs1466610710, COSV57150978; called by muse, mutect2, varscan2
- HAS1 | c.992G>A p.G331D | Missense Mutation (SNP) | VAF 162/394 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs749046036, COSV55787999; called by muse, varscan2
- HDC | c.1609G>A p.E537K | Missense Mutation (SNP) | VAF 212/323 reads (66%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs267604243; called by muse, mutect2, varscan2
- HELZ2 | c.7025C>T p.S2342F (on ENST00000467148 / NM_001037335.2; = p.S1773F on NM_033405.3) | Missense Mutation (SNP) | VAF 536/857 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as rs1211913458; called by muse, mutect2, varscan2
- HERC6 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 169/376 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs751533234; called by muse, mutect2, varscan2
- HHLA2 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 197/293 reads (67%) | SIFT tolerated (0.18); PolyPhen benign (0.148); catalogued as rs756495530; called by muse, mutect2, varscan2
- HRH1 | c.68C>T p.A23V | Missense Mutation (SNP) | VAF 205/545 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.154); catalogued as rs1052918272; called by muse, mutect2, varscan2
- HSPA2 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 263/596 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs957540010; called by muse, mutect2, varscan2
- HTR1B | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 178/474 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs1178706165; called by muse, mutect2, varscan2
- HTR1F | c.404G>A p.R135K | Missense Mutation (SNP) | VAF 208/482 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60391164; called by muse, mutect2, varscan2
- HTR7 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 211/321 reads (66%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.669); catalogued as COSV53288699; called by muse, mutect2, varscan2
- HTT | c.1621C>T p.P541S | Missense Mutation (SNP) | VAF 178/478 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.005); catalogued as rs781405304; called by muse, mutect2, varscan2
- HYDIN | c.12356C>T p.S4119F | Missense Mutation (SNP) | VAF 172/435 reads (40%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.466); catalogued as COSV66636817; called by muse, mutect2, varscan2
- HYDIN | c.7862C>T p.P2621L | Missense Mutation (SNP) | VAF 66/526 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs199737950, COSV59254986; called by muse, varscan2
- IARS1 | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 113/236 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100986899; called by muse, mutect2, varscan2
- IDO2 | c.823C>T p.H275Y (on ENST00000389060; = p.H288Y on NM_194294.2) | Missense Mutation (SNP) | VAF 195/459 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs544075736; called by muse, mutect2, varscan2
- IFNA17 | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 143/374 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.216); catalogued as rs1269424760, COSV101303490; called by muse, mutect2, varscan2
- IGKV1-6 | c.202C>T p.L68F | Missense Mutation (SNP) | VAF 688/1032 reads (67%) | SIFT deleterious (0.05); PolyPhen benign (0.109); catalogued as rs542893428; called by muse, mutect2, varscan2
- IGKV1-9 | c.86C>T p.S29F | Missense Mutation (SNP) | VAF 518/785 reads (66%) | SIFT deleterious (0); PolyPhen benign (0.409); catalogued as rs774540175; called by muse, mutect2, varscan2
- IGSF1 | c.3241G>A p.E1081K | Missense Mutation (SNP) | VAF 197/663 reads (30%) | SIFT tolerated (0.4); PolyPhen benign (0.145); catalogued as rs769535778, COSV63836135, COSV63837874; called by muse, mutect2, varscan2
- IL11RA | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 193/453 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201638429, COSV99426568; called by muse, mutect2, varscan2
- IL18RAP | c.181C>T p.R61* | Nonsense Mutation (SNP) | VAF 187/280 reads (67%) | catalogued as rs867163754, COSV51825422; called by muse, mutect2, varscan2
- IL1RAPL2 | c.1343G>A p.R448K | Missense Mutation (SNP) | VAF 93/315 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61158296; called by muse, mutect2, varscan2
- ILF3 | c.272G>A p.G91E | Missense Mutation (SNP) | VAF 192/483 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51554398; called by muse, mutect2, varscan2
- INHBA | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 230/313 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1157959739, COSV54219230; called by muse, mutect2, varscan2
- INPP5J | c.1945G>A p.E649K (on ENST00000331075 / NM_001284285.2; = p.E281K on NM_001002837.2) | Missense Mutation (SNP) | VAF 137/367 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58515355; called by muse, mutect2, varscan2
- INSYN2A | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 241/589 reads (41%) | SIFT tolerated (0.79); PolyPhen benign (0.023); catalogued as rs1301878478, COSV54752192; called by muse, mutect2, varscan2
- IQCF2 | c.353G>A p.R118Q | Missense Mutation (SNP) | VAF 209/545 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs201555465, COSV60761734; called by muse, mutect2, varscan2
- ITGB4 | c.1673C>T p.S558F | Missense Mutation (SNP) | VAF 146/450 reads (32%) | SIFT tolerated (0.7); PolyPhen benign (0.305); catalogued as COSV52324586; called by muse, mutect2, varscan2
- ITIH2 | c.1081G>A p.D361N | Missense Mutation (SNP) | VAF 221/306 reads (72%) | SIFT tolerated (0.37); PolyPhen benign (0.046); catalogued as rs532614781; called by muse, mutect2, varscan2
- ITSN1 | c.4844G>A p.G1615E | Missense Mutation (SNP) | VAF 122/258 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67156970; called by muse, mutect2, varscan2
- IVL | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 250/1317 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs1323795932; called by muse, mutect2, varscan2
- IZUMO3 | c.518G>A p.R173Q (on ENST00000543880 / NM_001365008.2; = p.R167Q on NM_001271706.1) | Missense Mutation (SNP) | VAF 137/364 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.412); catalogued as rs547586264; called by muse, varscan2
- JAK2 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 98/318 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.807); catalogued as rs764423560, COSV67579525; called by muse, mutect2, varscan2
- KCNA6 | c.746C>T p.S249F | Missense Mutation (SNP) | VAF 223/585 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as rs763515296, COSV54975553, COSV54977848; called by muse, mutect2, varscan2
- KCNJ4 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 241/546 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1569117881, COSV57856181; called by muse, mutect2, varscan2
- KCNK17 | c.991G>A p.D331N | Missense Mutation (SNP) | VAF 199/383 reads (52%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.272); catalogued as rs763883044; called by muse, mutect2, varscan2
- KCNMB2 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 103/155 reads (66%) | SIFT tolerated (0.14); PolyPhen benign (0.344); catalogued as COSV64201395; called by muse, mutect2, varscan2
- KCNU1 | c.2404C>T p.P802S | Missense Mutation (SNP) | VAF 197/461 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.005); catalogued as COSV101299008, COSV67753627; called by muse, mutect2, varscan2
- KHNYN | c.680C>T p.P227L | Missense Mutation (SNP) | VAF 234/534 reads (44%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as rs760232261, COSV52159120; called by muse, mutect2, varscan2
- KIF4B | c.883C>T p.R295* | Nonsense Mutation (SNP) | VAF 286/417 reads (69%) | catalogued as rs773641768, COSV70528458; called by muse, mutect2, varscan2
- KIF4B | c.2362C>T p.R788W | Missense Mutation (SNP) | VAF 197/272 reads (72%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs1011207360, COSV101469214; called by muse, mutect2, varscan2
- KIR3DL1 | c.356G>A p.G119E | Missense Mutation (SNP) | VAF 33/85 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV58494612; called by muse, mutect2, varscan2
- KLHDC3 | c.796C>T p.H266Y | Missense Mutation (SNP) | VAF 288/498 reads (58%) | SIFT deleterious (0.04); PolyPhen benign (0.011); catalogued as rs868120468; called by muse, mutect2, varscan2
- KLHL18 | c.46T>A p.S16T | Missense Mutation (SNP) | VAF 176/483 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs746645415; called by muse, mutect2
- KLK11 | c.822G>A p.W274* (on ENST00000594768 / NM_144947.3; = p.W242* on NM_006853.3) | Nonsense Mutation (SNP) | VAF 146/363 reads (40%) | catalogued as COSV59398028; called by muse, mutect2, varscan2
- KLRC2 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 91/477 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.076); catalogued as rs1469255630; called by muse, mutect2, varscan2
- KMT2D | c.14927C>T p.P4976L | Missense Mutation (SNP) | VAF 260/601 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs757859130; called by muse, mutect2, varscan2
- KRT36 | c.1258C>T p.P420S | Missense Mutation (SNP) | VAF 220/1021 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV60203450; called by muse, mutect2, varscan2
- KRT77 | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 197/526 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.2); catalogued as rs934846785; called by muse, mutect2, varscan2
- KRT80 | c.400G>A p.E134K | Missense Mutation (SNP) | VAF 179/522 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as rs757639013, COSV57548392; called by muse, mutect2, varscan2
- KRT85 | c.617G>A p.G206D | Missense Mutation (SNP) | VAF 118/353 reads (33%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.464); catalogued as COSV57736477; called by muse, mutect2, varscan2
- KRTAP10-3 | c.233C>T p.S78L | Missense Mutation (SNP) | VAF 342/837 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs181734444, COSV59954531; called by muse, mutect2, varscan2
- KRTAP5-8 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 306/1715 reads (18%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.013); catalogued as rs779049580; called by muse, mutect2, varscan2
- LAMA2 | c.5347G>A p.V1783I | Missense Mutation (SNP) | VAF 174/265 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs780686763; called by muse, mutect2, varscan2
- LAMA3 | c.2348C>T p.S783F | Missense Mutation (SNP) | VAF 99/313 reads (32%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.635); catalogued as COSV58083821; called by muse, mutect2, varscan2
- LAMC2 | c.781C>T p.Q261* | Nonsense Mutation (SNP) | VAF 129/178 reads (72%) | catalogued as CM062816, COSV51452016, COSV51458940; called by muse, mutect2, varscan2
- LETM2 | c.1400C>T p.S467F (on ENST00000379957 / NM_001286819.2; = p.S372F on NM_144652.3) | Missense Mutation (SNP) | VAF 147/374 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.358); catalogued as rs1402781354; called by muse, mutect2, varscan2
- LIFR | c.2752C>T p.P918S | Missense Mutation (SNP) | VAF 127/532 reads (24%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.834); catalogued as COSV54693785; called by muse, mutect2, varscan2
- LILRA4 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 225/878 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1200266591, COSV99393521; called by muse, mutect2, varscan2
- LILRA6 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 290/994 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.149); catalogued as COSV54439399, COSV99558787; called by muse, mutect2, varscan2
- LILRB1 | c.1607G>A p.R536Q (on ENST00000427581; = p.R486Q on NM_006669.6) | Missense Mutation (SNP) | VAF 210/536 reads (39%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs760007990, COSV61117500; called by muse, varscan2
- LIN7A | c.457G>A p.D153N | Missense Mutation (SNP) | VAF 145/367 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1175939523, COSV54019232; called by muse, mutect2, varscan2
- LMBRD2 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 161/579 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56948962; called by muse, mutect2, varscan2
- LRP12 | c.1966G>A p.D656N | Missense Mutation (SNP) | VAF 361/613 reads (59%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.989); catalogued as rs1325504116, COSV52636156; called by muse, mutect2, varscan2
- LRP12 | c.424C>T p.H142Y | Missense Mutation (SNP) | VAF 160/615 reads (26%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.988); catalogued as COSV52626214, COSV52627393; called by muse, mutect2, varscan2
- LRRC25 | c.910G>A p.G304R | Missense Mutation (SNP) | VAF 152/335 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs551461923, COSV53251649; called by muse, mutect2, varscan2
- LRRC70 | c.403C>T p.R135C | Missense Mutation (SNP) | VAF 88/191 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1454481157; called by muse, mutect2, varscan2
- LRRC9 | c.3046G>A p.E1016K | Missense Mutation (SNP) | VAF 73/209 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1428357163; called by muse, mutect2, varscan2
- LRRCC1 | c.1454C>T p.S485F | Missense Mutation (SNP) | VAF 201/331 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0.251); catalogued as COSV64485655; called by muse, mutect2, varscan2
- LRRN1 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 175/401 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1253954205, COSV60012923; called by muse, mutect2, varscan2
- LRRN1 | c.1420G>A p.D474N | Missense Mutation (SNP) | VAF 153/391 reads (39%) | SIFT tolerated (0.38); PolyPhen benign (0.16); catalogued as COSV60015111; called by muse, mutect2, varscan2
- LRTM2 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 187/463 reads (40%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs763791887; called by muse, mutect2, varscan2
- LTBP1 | c.4664G>A p.G1555E (on ENST00000404816 / NM_206943.4; = p.G1229E on NM_000627.4) | Missense Mutation (SNP) | VAF 204/493 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55382980; called by muse, mutect2, varscan2
- LYRM1 | c.365C>T p.S122F | Missense Mutation (SNP) | VAF 77/223 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99533925; called by muse, mutect2, varscan2
- MACF1 | c.14365C>T p.R4789C (on ENST00000372915; = p.R2722C on NM_012090.5) | Missense Mutation (SNP) | VAF 98/251 reads (39%) | catalogued as rs761855249, COSV57125823; called by muse, varscan2
- MACO1 | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 272/643 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.212); catalogued as rs1467916000, COSV65475005; called by muse, mutect2, varscan2
- MAGEB6 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 226/623 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.869); catalogued as COSV66871888, COSV66872013; called by muse, mutect2, varscan2
- MAGEL2 | c.3622G>A p.D1208N | Missense Mutation (SNP) | VAF 178/454 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.666); catalogued as COSV100045928; called by muse, mutect2, varscan2
- MALRD1 | c.3749C>T p.S1250F | Missense Mutation (SNP) | VAF 142/235 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.103); catalogued as COSV66005773; called by muse, mutect2, varscan2
- MAP3K9 | c.2611C>T p.P871S (on ENST00000554752 / NM_001284230.1; = p.P885S on NM_033141.4) | Missense Mutation (SNP) | VAF 452/783 reads (58%) | SIFT tolerated (0.09); PolyPhen benign (0.036); catalogued as rs955976237, COSV67121006; called by muse, mutect2, varscan2
- MAP3K9 | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 211/658 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs770841109, COSV67120353; called by muse, mutect2, varscan2
- MARCO | c.426G>A p.G142= | Splice Region (SNP) | VAF 175/482 reads (36%) | catalogued as COSV59054463; called by muse, mutect2, varscan2
- MARK2 | c.1859C>T p.P620L (on ENST00000402010 / NM_001039469.2; = p.P565L on NM_004954.5) | Missense Mutation (SNP) | VAF 230/333 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV59287988; called by muse, mutect2, varscan2
- MASP2 | c.917C>T p.P306L | Missense Mutation (SNP) | VAF 111/446 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1403726837; called by muse, mutect2, varscan2
- MAST1 | c.4153G>A p.D1385N | Missense Mutation (SNP) | VAF 217/541 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1486670625; called by muse, mutect2, varscan2
- MAST2 | c.1709C>T p.P570L | Missense Mutation (SNP) | VAF 157/379 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1221843860, COSV63619870; called by muse, mutect2, varscan2
- MAST3 | c.3584C>T p.S1195F | Missense Mutation (SNP) | VAF 202/519 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as rs1486954307; called by muse, mutect2, varscan2
- MBTPS2 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 172/509 reads (34%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.272); catalogued as rs777721295; called by muse, mutect2, varscan2
- MCTP1 | c.928G>A p.E310K | Missense Mutation (SNP) | VAF 138/360 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs1184193875, COSV56527514; called by muse, mutect2, varscan2
- MED23 | c.3178C>T p.P1060S | Missense Mutation (SNP) | VAF 184/262 reads (70%) | SIFT tolerated (0.79); PolyPhen benign (0.003); catalogued as COSV63431240; called by muse, mutect2, varscan2
- MEFV | c.449G>A p.G150E | Missense Mutation (SNP) | VAF 289/682 reads (42%) | SIFT tolerated (0.19); PolyPhen benign (0.254); catalogued as COSV54823252; called by muse, mutect2, varscan2
- MEI1 | c.1102G>A p.E368K | Missense Mutation (SNP) | VAF 91/231 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as rs1163707674; called by muse, mutect2, varscan2
- MESD | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 180/442 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.976); catalogued as rs762303952, COSV55725542; called by muse, mutect2, varscan2
- MEX3D | c.1241C>T p.S414F | Missense Mutation (SNP) | VAF 234/658 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.043); catalogued as rs1420550720; called by muse, mutect2, varscan2
- MGAM | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 108/277 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV72075912; called by muse, mutect2, varscan2
- MIIP | c.215C>T p.S72F | Missense Mutation (SNP) | VAF 233/872 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV52428727; called by muse, mutect2, varscan2
- MOGAT2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 94/1262 reads (7%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV52219974; called by muse, mutect2
- MPO | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 105/270 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs770768376; called by muse, mutect2, varscan2
- MR1 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 177/278 reads (64%) | SIFT deleterious (0.02); PolyPhen benign (0.073); catalogued as rs1259828561, COSV51579950; called by muse, mutect2, varscan2
- MRAP2 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 107/297 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV57632505; called by muse, mutect2, varscan2
- MRC1 | c.1426C>T p.R476W | Missense Mutation (SNP) | VAF 175/242 reads (72%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as rs782693726; called by muse, mutect2, varscan2
- MROH2B | c.4159G>A p.E1387K | Missense Mutation (SNP) | VAF 137/555 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.675); catalogued as rs774282086, COSV68184404, COSV68186473; called by muse, mutect2, varscan2
- MROH2B | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 131/295 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.223); catalogued as rs1030871074, COSV68183775; called by muse, mutect2, varscan2
- MROH2B | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 273/520 reads (53%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.994); catalogued as COSV101270697, COSV68180982; called by muse, mutect2, varscan2
- MRPL13 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 109/282 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.056); catalogued as rs781110831, COSV60369251; called by muse, mutect2, varscan2
- MRPS25 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 104/310 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs767284384; called by muse, mutect2, varscan2
- MSRB3 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 159/457 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.184); catalogued as COSV57591804; called by muse, mutect2, varscan2
- MUC12 | c.2509G>A p.G837S (on ENST00000379442; = p.G694S on NM_001164462.1) | Missense Mutation (SNP) | VAF 158/879 reads (18%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.86); catalogued as rs1300870816; called by muse, mutect2, varscan2
- MUC16 | c.26723C>T p.S8908L | Missense Mutation (SNP) | VAF 144/351 reads (41%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.017); catalogued as COSV67462039; called by muse, mutect2, varscan2
- MUC16 | c.22414C>T p.H7472Y | Missense Mutation (SNP) | VAF 172/434 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.332); catalogued as rs1195832019, COSV67461492; called by muse, varscan2
- MUC16 | c.22303G>A p.E7435K | Missense Mutation (SNP) | VAF 196/452 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.02); catalogued as rs768933832; called by muse, varscan2
- MUC16 | c.20461C>T p.P6821S | Missense Mutation (SNP) | VAF 155/380 reads (41%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.254); catalogued as rs61997222; called by muse, mutect2, varscan2
- MUC16 | c.18401C>T p.S6134L | Missense Mutation (SNP) | VAF 152/421 reads (36%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.01); catalogued as COSV67447839; called by muse, mutect2, varscan2
- MUC16 | c.16610C>T p.P5537L | Missense Mutation (SNP) | VAF 209/506 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV67479699; called by muse, mutect2, varscan2
- MUC16 | c.12374C>T p.T4125M | Missense Mutation (SNP) | VAF 173/452 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs577056863, COSV67471943; called by muse, mutect2, varscan2
- MUC16 | c.7979C>T p.S2660L | Missense Mutation (SNP) | VAF 159/382 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.765); catalogued as rs896919022, COSV67476351, COSV67482941; called by muse, mutect2, varscan2
- MUC16 | c.3515C>T p.S1172L | Missense Mutation (SNP) | VAF 180/487 reads (37%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.112); catalogued as COSV67462867; called by muse, mutect2, varscan2
- MUC4 | c.5524C>T p.P1842S | Missense Mutation (SNP) | VAF 220/1128 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.65); catalogued as rs1470943216, COSV62174025; called by muse, mutect2, varscan2
- MUC4 | c.38C>T p.S13F | Missense Mutation (SNP) | VAF 251/336 reads (75%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.496); catalogued as rs1209725692; called by muse, mutect2, varscan2
- MUC7 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 54/168 reads (32%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0.19); catalogued as rs186414931, COSV100512189; called by muse, mutect2, varscan2
- MYBL1 | c.1291C>T p.P431S | Missense Mutation (SNP) | VAF 226/785 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV72918804, COSV72919253; called by muse, mutect2, varscan2
- MYH6 | c.3116C>T p.S1039F | Missense Mutation (SNP) | VAF 130/398 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1398042911, COSV62448284, COSV62449858; called by muse, mutect2, varscan2
- MYO3A | c.2183C>T p.S728F | Missense Mutation (SNP) | VAF 137/196 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761351165, COSV56323712, COSV99780626; called by muse, mutect2, varscan2
- MYO7A | c.4159G>A p.D1387N | Missense Mutation (SNP) | VAF 119/623 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs749881235, COSV68685852; called by muse, mutect2, varscan2
- MYO7A | c.5033G>A p.R1678Q | Missense Mutation (SNP) | VAF 82/668 reads (12%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs371115266; ClinVar: uncertain significance; called by muse, varscan2
- MYRFL | c.1730G>T p.S577I | Missense Mutation (SNP) | VAF 127/350 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs1031480459; called by mutect2, varscan2
- MYRFL | c.2546G>A p.R849K | Missense Mutation (SNP) | VAF 112/253 reads (44%) | SIFT tolerated (0.4); PolyPhen benign (0.005); catalogued as COSV100185064; called by muse, mutect2, varscan2
- MYT1L | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 154/566 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV67735792; called by muse, mutect2, varscan2
- NCOA1 | c.1163C>T p.P388L | Missense Mutation (SNP) | VAF 144/400 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as COSV56044359, COSV99946783; called by muse, mutect2, varscan2
- NCOA5 | c.193_219del p.H65_R73del | In Frame Del (DEL) | VAF 696/1087 reads (64%) | catalogued as rs1434016379; called by mutect2, pindel, varscan2
- NEGR1 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 179/369 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60833285; called by muse, mutect2, varscan2
- NEU4 | c.607G>A p.D203N (on ENST00000391969 / NM_001167602.3; = p.D215N on NM_080741.4) | Missense Mutation (SNP) | VAF 300/429 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs762057533, COSV57991676; called by muse, mutect2, varscan2
- NF1 | c.2428A>T p.K810* | Nonsense Mutation (SNP) | VAF 85/247 reads (34%) | catalogued as CM021310, CP005300, COSV62196453; called by muse, mutect2, varscan2
- NF1 | c.6733C>T p.Q2245* (on ENST00000358273 / NM_001042492.3; = p.Q2224* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 129/330 reads (39%) | catalogued as CS1311544; called by muse, mutect2, varscan2
- NFATC3 | c.3055C>T p.R1019* | Nonsense Mutation (SNP) | VAF 115/333 reads (35%) | catalogued as rs1332382073, COSV60476722; called by muse, mutect2, varscan2
- NISCH | c.4495C>T p.P1499S | Missense Mutation (SNP) | VAF 150/397 reads (38%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as rs759153416; called by muse, mutect2, varscan2
- NKD1 | c.916C>T p.P306S | Missense Mutation (SNP) | VAF 191/522 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.082); catalogued as COSV51694584; called by muse, mutect2, varscan2
- NLGN4X | c.2006G>A p.R669Q | Missense Mutation (SNP) | VAF 211/532 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.03); catalogued as COSV52008892; called by muse, mutect2, varscan2
- NLRP13 | c.2887G>A p.D963N | Missense Mutation (SNP) | VAF 203/519 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as rs267605701, COSV61620184; called by muse, mutect2, varscan2
- NLRP14 | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 111/302 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.113); catalogued as COSV55073136; called by muse, mutect2, varscan2
- NLRP2 | c.3073G>A p.D1025N | Missense Mutation (SNP) | VAF 111/299 reads (37%) | SIFT tolerated (0.52); PolyPhen benign (0.274); catalogued as rs1467652508; called by muse, mutect2, varscan2
- NLRP9 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 164/432 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV60464247; called by muse, mutect2, varscan2
- NOBOX | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 146/383 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); catalogued as COSV56197331; called by muse, mutect2, varscan2
- NPAT | c.2252C>T p.S751F | Missense Mutation (SNP) | VAF 161/226 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99586247; called by muse, mutect2, varscan2
- NPIPB2 | c.997G>A p.E333K (on ENST00000399147; = p.E193K on NM_001355514.1) | Missense Mutation (SNP) | VAF 223/563 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.799); catalogued as rs1403521022; called by muse, mutect2, varscan2
- NRK | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 189/439 reads (43%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.845); catalogued as rs751406404, COSV54599088, COSV99686747; called by muse, mutect2, varscan2
- NRK | c.2633G>A p.G878E | Missense Mutation (SNP) | VAF 104/255 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.661); catalogued as rs1264947514, COSV54600516; called by muse, mutect2, varscan2
- NRXN3 | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 172/625 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.743); catalogued as COSV55335097; called by muse, varscan2
- NTF3 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 229/568 reads (40%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as COSV58417248; called by muse, mutect2, varscan2
- NTN4 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 138/303 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1247651947, COSV59219722; called by muse, mutect2, varscan2
- NTNG2 | c.98C>T p.T33I | Missense Mutation (SNP) | VAF 192/486 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as COSV100647895; called by muse, mutect2, varscan2
- NUDT14 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 410/697 reads (59%) | SIFT tolerated (0.67); PolyPhen benign (0.098); catalogued as rs1019049412; called by muse, mutect2, varscan2
- NUDT17 | c.353C>T p.S118F | Missense Mutation (SNP) | VAF 588/820 reads (72%) | SIFT tolerated (0.58); PolyPhen benign (0.012); catalogued as rs782152369; called by muse, mutect2, varscan2
- NUMA1 | c.2129C>T p.S710F | Missense Mutation (SNP) | VAF 224/1241 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as rs1290455590; called by muse, mutect2, varscan2
- NUP188 | c.3457C>T p.L1153F | Missense Mutation (SNP) | VAF 151/392 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as rs1280737709; called by muse, mutect2, varscan2
- NUP98 | c.3314C>T p.P1105L (on ENST00000359171 / NM_001365126.1; = p.P1088L on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 228/319 reads (71%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs146515319, COSV61432382; called by muse, mutect2, varscan2
- NUTM2D | c.1835G>A p.R612Q | Missense Mutation (SNP) | VAF 215/685 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs775312385; called by muse, mutect2, varscan2
- NWD1 | c.2270C>T p.S757F | Missense Mutation (SNP) | VAF 143/391 reads (37%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.467); catalogued as COSV60337354; called by muse, mutect2, varscan2
- NYAP1 | c.2038C>T p.P680S | Missense Mutation (SNP) | VAF 249/626 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1400165055; called by muse, mutect2, varscan2
- OLFM4 | c.1144G>A p.D382N | Missense Mutation (SNP) | VAF 178/508 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV99524500; called by muse, mutect2, varscan2
- OR10AD1 | c.821C>G p.P274R | Missense Mutation (SNP) | VAF 195/489 reads (40%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.522); catalogued as COSV59613059; called by muse, mutect2, varscan2
- OR10J3 | c.803C>T p.S268F | Missense Mutation (SNP) | VAF 220/1063 reads (21%) | SIFT deleterious (0.05); PolyPhen benign (0.104); catalogued as rs868734843, COSV59953696, COSV59955976; called by muse, mutect2, varscan2
- OR11H12 | c.493G>A p.V165I | Missense Mutation (SNP) | VAF 235/1885 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.039); catalogued as rs1465980547; called by muse, mutect2, varscan2
- OR13D1 | c.622C>T p.H208Y | Missense Mutation (SNP) | VAF 181/407 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as COSV59513528, COSV59515030; called by muse, mutect2, varscan2
- OR1D2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 199/266 reads (75%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs767444459, COSV58921027; called by muse, mutect2, varscan2
- OR1E1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 219/324 reads (68%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as rs749244072, COSV59458508; called by muse, mutect2, varscan2
- OR1J1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 118/317 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.831); catalogued as rs768235840; called by muse, mutect2, varscan2
- OR1J2 | c.272C>T p.S91L | Missense Mutation (SNP) | VAF 155/422 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.29); catalogued as rs759405491, COSV58944649; called by muse, mutect2, varscan2
- OR1M1 | c.311T>C p.F104S | Missense Mutation (SNP) | VAF 230/513 reads (45%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs764485242; called by muse, mutect2, varscan2
- OR1M1 | c.447G>A p.W149* | Nonsense Mutation (SNP) | VAF 187/479 reads (39%) | catalogued as COSV70037118; called by muse, mutect2, varscan2
- OR2A12 | c.926C>T p.S309L | Missense Mutation (SNP) | VAF 120/274 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs769397640, COSV68821096; called by muse, mutect2, varscan2
- OR2A2 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 200/481 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV68871986; called by muse, mutect2, varscan2
- OR2AJ1 | c.47G>A p.G16E | Missense Mutation (SNP) | VAF 148/227 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs866778851; called by muse, mutect2, varscan2
- OR2AP1 | c.812G>A p.G271E | Missense Mutation (SNP) | VAF 163/403 reads (40%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.174); catalogued as rs752292621; called by muse, mutect2, varscan2
- OR2S2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 189/490 reads (39%) | SIFT tolerated (0.06); PolyPhen benign (0.226); catalogued as rs750104095, COSV59530882; called by muse, mutect2, varscan2
- OR4C16 | c.250C>T p.L84F | Missense Mutation (SNP) | VAF 142/234 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as rs376544054, COSV58940943; called by muse, mutect2, varscan2
- OR4K13 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 172/381 reads (45%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs202203700, COSV59859121; called by muse, mutect2, varscan2
- OR51V1 | c.586C>T p.R196* | Nonsense Mutation (SNP) | VAF 199/288 reads (69%) | catalogued as rs142365861; called by muse, mutect2, varscan2
- OR5L2 | c.898G>A p.A300T | Missense Mutation (SNP) | VAF 109/178 reads (61%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV65723687; called by muse, mutect2, varscan2
- OR6C2 | c.310C>T p.L104F | Missense Mutation (SNP) | VAF 190/439 reads (43%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.013); catalogued as COSV59515933, COSV59516354; called by muse, mutect2, varscan2
- OR7G2 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 176/442 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs759343004, COSV59688755; called by muse, mutect2, varscan2
- OR8D4 | c.135G>A p.M45I | Missense Mutation (SNP) | VAF 187/284 reads (66%) | SIFT deleterious (0.04); PolyPhen benign (0.056); catalogued as rs150490501, COSV58431392; called by muse, mutect2, varscan2
- OR8G5 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 75/122 reads (61%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.611); catalogued as rs549702172, COSV100422343; called by muse, mutect2, varscan2
- OR8K1 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 201/294 reads (68%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.744); catalogued as COSV54403400; called by muse, mutect2, varscan2
- OR9K2 | c.409G>A p.G137R (on ENST00000305377; = p.G115R on NM_001005243.1) | Missense Mutation (SNP) | VAF 206/507 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV59532936; called by muse, mutect2, varscan2
- ORC1 | c.1132C>T p.R378C | Missense Mutation (SNP) | VAF 162/567 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs769313282, COSV65363479, COSV65364640; called by muse, mutect2, varscan2
- OTOF | c.1498C>T p.R500* | Nonsense Mutation (SNP) | VAF 153/453 reads (34%) | catalogued as rs773543852; called by muse, mutect2, varscan2
- OTOGL | c.3775C>T p.P1259S (on ENST00000547103; = p.P1250S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 75/210 reads (36%) | SIFT tolerated (0.48); PolyPhen benign (0.406); catalogued as COSV101509177; called by muse, mutect2, varscan2
- OVGP1 | c.379C>T p.L127F | Missense Mutation (SNP) | VAF 375/664 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as rs749276169, COSV63857918; called by muse, mutect2, varscan2
- PACSIN1 | c.1129G>A p.G377S | Missense Mutation (SNP) | VAF 204/724 reads (28%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.449); catalogued as rs778245556; called by muse, mutect2, varscan2
- PAFAH1B3 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 166/380 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1242789007; called by muse, mutect2, varscan2
- PAH | c.1076C>T p.S359L | Missense Mutation (SNP) | VAF 119/299 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as CM1511451, CM930561; called by muse, mutect2
- PAK5 | c.1786G>A p.E596K | Missense Mutation (SNP) | VAF 162/387 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.527); catalogued as COSV62034115; called by muse, mutect2, varscan2
- PALM3 | c.641G>A p.G214E (on ENST00000340790; = p.G229E on NM_001145028.2) | Missense Mutation (SNP) | VAF 241/593 reads (41%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.993); catalogued as rs1475010485; called by muse, mutect2, varscan2
- PAPPA2 | c.1877G>A p.G626E | Missense Mutation (SNP) | VAF 209/302 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62775157; called by muse, mutect2, varscan2
- PAX1 | c.1355G>A p.R452Q | Missense Mutation (SNP) | VAF 194/472 reads (41%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.143); catalogued as COSV68272004; called by muse, varscan2
- PAX8 | c.659G>A p.R220Q | Missense Mutation (SNP) | VAF 184/512 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.457); catalogued as rs919587560, COSV99638956; called by muse, mutect2, varscan2
- PCBP2 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 116/268 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as COSV63728370; called by muse, mutect2, varscan2
- PCDH15 | c.5342C>A p.P1781H | Missense Mutation (SNP) | VAF 120/172 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.478); catalogued as COSV100226457; called by muse, mutect2, varscan2
- PCDH15 | c.5341C>T p.P1781S | Missense Mutation (SNP) | VAF 122/174 reads (70%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.003); catalogued as rs938596168, COSV57357456; called by muse, mutect2, varscan2
- PCMTD1 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 92/412 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749921649; called by muse, varscan2
- PCSK1 | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 107/335 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.676); catalogued as COSV60736693; called by muse, mutect2, varscan2
- PCYT1B | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 132/304 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.945); catalogued as COSV63266725; called by muse, mutect2, varscan2
- PDE1C | c.19G>A p.E7K | Missense Mutation (SNP) | VAF 103/146 reads (71%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV58502752; called by muse, mutect2, varscan2
- PDE3A | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 171/411 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62969798; called by muse, mutect2, varscan2
- PDE7B | c.796G>A p.E266K | Missense Mutation (SNP) | VAF 132/192 reads (69%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.888); catalogued as rs867250176, COSV57504620; called by muse, varscan2
- PHACTR3 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 828/1247 reads (66%) | SIFT tolerated (0.66); PolyPhen benign (0.009); catalogued as rs540716594; called by muse, mutect2, varscan2
- PHC3 | c.2509C>T p.R837C (on ENST00000494943 / NM_001308116.2; = p.R849C on NM_024947.4) | Missense Mutation (SNP) | VAF 157/226 reads (69%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs779146351; called by muse, mutect2, varscan2
- PIK3C2G | c.2902C>T p.R968C (on ENST00000676171; = p.R927C on NM_004570.5) | Missense Mutation (SNP) | VAF 108/292 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs368805708; called by muse, mutect2, varscan2
- PIK3CG | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 199/528 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.19); catalogued as rs761655879, COSV63245816; called by muse, mutect2, varscan2
- PITPNM1 | c.1802C>T p.P601L | Missense Mutation (SNP) | VAF 173/639 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs776940244, COSV62709727; called by muse, mutect2, varscan2
- PKD1 | c.10361C>T p.S3454F (on ENST00000262304 / NM_001009944.3; = p.S3453F on NM_000296.4) | Missense Mutation (SNP) | VAF 252/652 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); catalogued as rs936935168; called by muse, mutect2, varscan2
- PKD1L1 | c.7214C>T p.P2405L | Missense Mutation (SNP) | VAF 14/532 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.041); catalogued as rs1163708902; called by muse, mutect2
- PKD2L1 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 190/302 reads (63%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as COSV58396324; called by muse, mutect2, varscan2
- PKD2L2 | c.394C>T p.R132C | Missense Mutation (SNP) | VAF 185/461 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs368989091; called by muse, mutect2, varscan2
- PKHD1L1 | c.1889G>A p.G630E | Missense Mutation (SNP) | VAF 157/460 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV101007256, COSV65738689; called by muse, mutect2
- PKHD1L1 | c.10705C>T p.P3569S | Missense Mutation (SNP) | VAF 136/316 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.014); catalogued as rs866043029, COSV65740670; called by muse, mutect2, varscan2
- PLCB1 | c.2258G>A p.G753E | Missense Mutation (SNP) | VAF 150/436 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV62052208; called by muse, mutect2, varscan2
- PLD2 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 126/185 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV54006030; called by muse, mutect2, varscan2
- PLEKHG4B | c.2290G>A p.E764K (on ENST00000283426; = p.E1120K on NM_052909.5) | Missense Mutation (SNP) | VAF 488/590 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.604); catalogued as COSV52044104, COSV99359917; called by muse, mutect2, varscan2
- PLIN4 | c.187G>A p.E63K (on ENST00000301286; = p.E78K on NM_001367868.2) | Missense Mutation (SNP) | VAF 244/626 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs770270740, COSV100013810; called by muse, mutect2, varscan2
- PLXNA4 | c.1381G>A p.D461N | Missense Mutation (SNP) | VAF 136/355 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.144); catalogued as COSV58114490, COSV58146744; called by muse, mutect2, varscan2
- PMVK | c.157C>T p.Q53* | Nonsense Mutation (SNP) | VAF 116/712 reads (16%) | catalogued as rs1228955826; called by muse, mutect2, varscan2
- POM121L2 | c.600G>A p.M200I | Missense Mutation (SNP) | VAF 178/695 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV66277317; called by muse, mutect2, varscan2
- POTEI | c.466G>A p.D156N | Missense Mutation (SNP) | VAF 64/276 reads (23%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.21); catalogued as rs758683420; called by muse, mutect2, varscan2
- PPARGC1A | c.520C>T p.H174Y | Missense Mutation (SNP) | VAF 101/298 reads (34%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); catalogued as rs267600131; called by muse, mutect2, varscan2
- PPFIA2 | c.3301G>A p.E1101K | Missense Mutation (SNP) | VAF 110/285 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.148); catalogued as rs1324448691, COSV61040466; called by muse, mutect2, varscan2
- PPFIA2 | c.3005G>A p.G1002E | Missense Mutation (SNP) | VAF 106/301 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs866768312; called by muse, mutect2, varscan2
- PPP1R9A | c.2669C>T p.S890F | Missense Mutation (SNP) | VAF 179/513 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.543); catalogued as COSV99195288; called by muse, mutect2, varscan2
- PPP6R2 | c.2116G>A p.G706S (on ENST00000216061 / NM_001365836.1; = p.G679S on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 135/320 reads (42%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1472164999; called by muse, mutect2, varscan2
- PRAMEF19 | c.1006C>T p.R336C | Missense Mutation (SNP) | VAF 348/689 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.594); catalogued as rs754660509, COSV65819448; called by muse, varscan2
- PRDM16 | c.2170G>A p.A724T | Missense Mutation (SNP) | VAF 219/598 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs749126430, COSV54591576; called by muse, mutect2, varscan2
- PRKAB1 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 110/258 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs867491740; called by muse, mutect2, varscan2
- PROKR2 | c.740C>T p.S247F | Missense Mutation (SNP) | VAF 211/545 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV54086790; called by muse, mutect2, varscan2
- PRR23B | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 255/383 reads (67%) | SIFT tolerated (0.13); PolyPhen benign (0.277); catalogued as COSV61494918; called by muse, mutect2, varscan2
- PRSS8 | c.592C>A p.R198S | Missense Mutation (SNP) | VAF 207/515 reads (40%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.986); catalogued as COSV54898674; called by muse, mutect2, varscan2
- PSG2 | c.740C>T p.S247L | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.08); PolyPhen benign (0.14); catalogued as COSV61546023; called by muse, mutect2, varscan2
- PSG6 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 190/520 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.17); catalogued as COSV51830662, COSV99413742; called by muse, mutect2, varscan2
- PSG7 | c.851C>T p.P284L | Missense Mutation (SNP) | VAF 263/693 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV68446616; called by muse, mutect2, varscan2
- PSG8 | c.1048C>T p.L350F | Missense Mutation (SNP) | VAF 159/445 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1406472449, COSV60615623; called by muse, mutect2, varscan2
- PSMD3 | c.620C>T p.A207V | Missense Mutation (SNP) | VAF 275/577 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.019); catalogued as COSV52858707; called by muse, mutect2, varscan2
- PSMD8 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 237/559 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs867351891; called by muse, mutect2, varscan2
- PTGFRN | c.1013C>T p.S338F | Missense Mutation (SNP) | VAF 180/691 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as rs1162235874, COSV67798989; called by muse, mutect2, varscan2
- PTMA | c.118-1G>A p.X40_splice | Splice Site (SNP) | VAF 113/302 reads (37%) | catalogued as COSV100398420; called by muse, mutect2, varscan2
- PTPN13 | c.3704C>G p.P1235R (on ENST00000411767 / NM_080683.3; = p.P1216R on NM_006264.3) | Missense Mutation (SNP) | VAF 58/291 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV57407058; called by muse, mutect2, varscan2
- PTPN2 | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 115/326 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1203900630; called by muse, mutect2, varscan2
- PTPRB | c.3874G>A p.D1292N | Missense Mutation (SNP) | VAF 176/506 reads (35%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.924); catalogued as rs1250884124, COSV54242050; called by muse, mutect2, varscan2
- PTPRD | c.4855G>A p.E1619K | Missense Mutation (SNP) | VAF 216/535 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs776356704, COSV61925042, COSV61929950; called by muse, mutect2, varscan2
- PTPRD | c.3865C>T p.L1289F | Missense Mutation (SNP) | VAF 97/261 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as COSV100645358; called by muse, mutect2, varscan2
- PTPRD | c.686G>A p.R229Q | Missense Mutation (SNP) | VAF 130/342 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.279); catalogued as COSV61953382, COSV61976425; called by muse, mutect2, varscan2
- PTPRD | c.608G>A p.G203E | Missense Mutation (SNP) | VAF 123/341 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100645038, COSV61926901; called by muse, mutect2, varscan2
- PTPRT | c.2680G>A p.E894K | Missense Mutation (SNP) | VAF 114/267 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs746391800, COSV100629645; called by muse, mutect2, varscan2
- PTPRT | c.1853G>A p.G618E | Missense Mutation (SNP) | VAF 139/363 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV61983568; called by muse, mutect2, varscan2
- PUS10 | c.214C>T p.R72* | Nonsense Mutation (SNP) | VAF 135/349 reads (39%) | catalogued as rs759814796, COSV57453053; called by muse, mutect2, varscan2
- PXDNL | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 240/1214 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.034); catalogued as COSV62488824; called by muse, mutect2
- RAB11FIP1 | c.2761A>T p.T921S | Missense Mutation (SNP) | VAF 217/504 reads (43%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.041); catalogued as rs1241598236; called by muse, mutect2, varscan2
- RAB3GAP1 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 112/376 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV99920972; called by muse, mutect2, varscan2
- RALBP1 | c.1358C>T p.T453I | Missense Mutation (SNP) | VAF 106/294 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as rs1351728725; called by muse, mutect2, varscan2
- RALYL | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 200/682 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs774536609, COSV72819620; called by muse, mutect2, varscan2
- RALYL | c.573G>A p.L191= | Splice Region (SNP) | VAF 109/359 reads (30%) | catalogued as COSV72823864; called by muse, mutect2, varscan2
- RAPGEF4 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 135/309 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs938937021, COSV51413829, COSV99911116; called by muse, mutect2, varscan2
- RAPGEF4 | c.862C>T p.R288* | Nonsense Mutation (SNP) | VAF 150/383 reads (39%) | catalogued as COSV99910822; called by muse, mutect2, varscan2
- RASGRP3 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 89/232 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.347); catalogued as rs1370844290; called by muse, mutect2, varscan2
- RBM42 | c.539C>T p.P180L | Missense Mutation (SNP) | VAF 204/498 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV52898482; called by muse, mutect2, varscan2
- RBP3 | c.2692G>A p.A898T | Missense Mutation (SNP) | VAF 204/326 reads (63%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.519); catalogued as rs1555211528; called by muse, mutect2, varscan2
- RBP5 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 99/260 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs187594426, COSV99866616; called by muse, mutect2, varscan2
- RCBTB2 | c.696C>G p.N232K | Missense Mutation (SNP) | VAF 128/333 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60650346; called by muse, mutect2, varscan2
- RECK | c.406-1G>A p.X136_splice | Splice Site (SNP) | VAF 63/213 reads (30%) | catalogued as COSV65036315; called by muse, mutect2, varscan2
- REEP2 | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 158/351 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); catalogued as rs1424661039, COSV54734988; called by muse, mutect2, varscan2
- REG3A | c.364T>G p.W122G | Missense Mutation (SNP) | VAF 113/447 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59408747; called by muse, mutect2, varscan2
- REPS1 | c.428C>T p.S143F | Missense Mutation (SNP) | VAF 179/267 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV99238606; called by muse, mutect2, varscan2
- REXO1 | c.2416C>T p.P806S | Missense Mutation (SNP) | VAF 90/238 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.336); catalogued as rs369983700; called by muse, mutect2, varscan2
- RGPD3 | c.4198G>A p.D1400N | Missense Mutation (SNP) | VAF 200/482 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1247583441, COSV58748209; called by muse, mutect2, varscan2
- RIMS1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 194/506 reads (38%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.452); catalogued as rs866875897, COSV53441814; called by muse, mutect2
- RIN3 | c.2944C>T p.P982S | Missense Mutation (SNP) | VAF 178/616 reads (29%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.091); catalogued as rs764089654; called by muse, mutect2, varscan2
- RMND5A | c.1051A>G p.K351E | Missense Mutation (SNP) | VAF 166/606 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as rs1472492467; called by muse, mutect2, varscan2
- RNF180 | c.1567C>T p.H523Y | Missense Mutation (SNP) | VAF 98/264 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV66632738; called by muse, mutect2, varscan2
- ROBO2 | c.2359C>T p.H787Y | Missense Mutation (SNP) | VAF 154/341 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.194); catalogued as rs1424330409; called by muse, mutect2, varscan2
- ROBO2 | c.4049G>A p.R1350K | Missense Mutation (SNP) | VAF 177/470 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs1170041787; called by muse, mutect2, varscan2
- RP1 | c.760G>A p.G254R | Missense Mutation (SNP) | VAF 125/579 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55109499, COSV55116849; called by muse, mutect2, varscan2
- RP1 | c.2314G>A p.G772R | Missense Mutation (SNP) | VAF 222/384 reads (58%) | SIFT tolerated (0.64); PolyPhen benign (0.082); catalogued as COSV55123782; called by muse, mutect2, varscan2
- RP1 | c.5099G>A p.R1700K | Missense Mutation (SNP) | VAF 198/870 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99607744; called by muse, mutect2
- RP1 | c.3131G>A p.G1044E | Missense Mutation (SNP) | VAF 124/711 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1187269372, COSV73139032; called by muse, mutect2, varscan2
- RPGRIP1 | c.3448G>A p.D1150N | Missense Mutation (SNP) | VAF 171/444 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs144704092; called by muse, mutect2, varscan2
- RPH3A | c.986G>A p.R329Q (on ENST00000389385 / NM_001143854.2; = p.R325Q on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 222/531 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.072); catalogued as rs768544460, COSV66990364; called by muse, mutect2, varscan2
- RPTN | c.713C>T p.S238F | Missense Mutation (SNP) | VAF 190/1093 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.085); catalogued as COSV60166511; called by muse, mutect2, varscan2
- RYR1 | c.5446G>A p.G1816R | Missense Mutation (SNP) | VAF 235/595 reads (39%) | SIFT tolerated (0.14); PolyPhen benign (0.082); catalogued as COSV62109820; called by muse, mutect2, varscan2
- RYR1 | c.5719G>A p.E1907K | Missense Mutation (SNP) | VAF 250/648 reads (39%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV62087289, COSV62099169; called by muse, mutect2, varscan2
- SALL1 | c.2023C>T p.P675S | Missense Mutation (SNP) | VAF 214/521 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs868718687, COSV51753329, COSV51757244; called by muse, mutect2, varscan2
- SCG3 | c.130G>A p.E44K | Missense Mutation (SNP) | VAF 89/149 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1292269258, COSV55020489; called by muse, mutect2, varscan2
- SCG5 | c.458C>T p.P153L (on ENST00000300175 / NM_001144757.2; = p.P152L on NM_003020.4) | Missense Mutation (SNP) | VAF 220/310 reads (71%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs202071901, COSV55707627; called by muse, mutect2, varscan2
- SCN10A | c.5365G>A p.D1789N | Missense Mutation (SNP) | VAF 222/497 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs375735101; called by muse, mutect2, varscan2
- SCN11A | c.4685G>A p.R1562Q | Missense Mutation (SNP) | VAF 153/419 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs771220857, COSV56565664, COSV56573959; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SCN2A | c.263A>G p.K88R | Missense Mutation (SNP) | VAF 62/193 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.41); catalogued as COSV51843362, COSV99032435; called by muse, mutect2, varscan2
- SCNN1D | c.1369G>A p.E457K (on ENST00000338555; = p.E621K on NM_001130413.4) | Missense Mutation (SNP) | VAF 151/405 reads (37%) | SIFT tolerated (0.33); PolyPhen benign (0.374); catalogued as rs768787204; called by muse, mutect2, varscan2
- SEC14L5 | c.178C>T p.R60W | Missense Mutation (SNP) | VAF 187/533 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as rs375888958; called by muse, mutect2, varscan2
- SEC14L5 | c.1375G>A p.G459R | Missense Mutation (SNP) | VAF 215/533 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1237049714, COSV52038253; called by muse, mutect2, varscan2
- SEC16A | c.2324C>T p.S775L | Missense Mutation (SNP) | VAF 162/491 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as rs747047662; called by muse, mutect2, varscan2
- SEPSECS | c.1132A>G p.K378E | Missense Mutation (SNP) | VAF 179/404 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV57208199; called by muse, mutect2, varscan2
- SERPINB10 | c.310G>A p.D104N | Missense Mutation (SNP) | VAF 175/472 reads (37%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs200550911; called by muse, mutect2, varscan2
- SERPINB13 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 171/475 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54028036; called by muse, mutect2, varscan2
- SERPINF1 | c.1249G>A p.G417S | Missense Mutation (SNP) | VAF 103/155 reads (66%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as rs1212326007; called by muse, mutect2, varscan2
- SERPINI1 | c.64C>T p.P22S | Missense Mutation (SNP) | VAF 161/222 reads (73%) | SIFT tolerated (0.43); PolyPhen benign (0.147); catalogued as COSV55512186; called by muse, mutect2, varscan2
- SESN2 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 216/504 reads (43%) | SIFT tolerated (0.92); PolyPhen benign (0.072); catalogued as rs774449109, COSV53427234; called by muse, mutect2, varscan2
- SETD5 | c.3077C>T p.S1026F | Missense Mutation (SNP) | VAF 117/324 reads (36%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV56711090; called by mutect2, varscan2
- SEZ6L2 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 191/546 reads (35%) | SIFT tolerated (1); PolyPhen possibly damaging (0.481); catalogued as rs757724567; called by muse, mutect2, varscan2
- SFTA2 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 388/707 reads (55%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.072); catalogued as rs781452586; called by muse, mutect2, varscan2
- SH3GL3 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 138/380 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs142360966; called by muse, mutect2, varscan2
- SHANK2 | c.2534G>A p.R845Q | Missense Mutation (SNP) | VAF 168/698 reads (24%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.49); catalogued as rs782015001, COSV53585885; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SHROOM2 | c.2056G>A p.E686K | Missense Mutation (SNP) | VAF 274/725 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV66611590; called by muse, mutect2, varscan2
- SIPA1L2 | c.3479C>T p.P1160L | Missense Mutation (SNP) | VAF 228/320 reads (71%) | SIFT tolerated (0.08); PolyPhen benign (0.03); catalogued as rs1406639665; called by muse, mutect2, varscan2
- SIRT6 | c.914C>T p.T305I | Missense Mutation (SNP) | VAF 175/439 reads (40%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs1275362106; called by muse, mutect2, varscan2
- SKI | c.1484C>T p.S495F | Missense Mutation (SNP) | VAF 138/318 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV66013356; called by muse, mutect2, varscan2
- SLC10A2 | c.7G>A p.D3N | Missense Mutation (SNP) | VAF 79/259 reads (31%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs866026770, COSV55358409; called by muse, mutect2, varscan2
- SLC12A6 | c.1727C>T p.S576F (on ENST00000354181 / NM_001365088.1; = p.S525F on NM_005135.2) | Missense Mutation (SNP) | VAF 220/307 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.688); catalogued as rs1244030823; called by muse, mutect2, varscan2
- SLC14A2 | c.377C>T p.T126I | Missense Mutation (SNP) | VAF 160/247 reads (65%) | SIFT tolerated (0.87); PolyPhen benign (0.305); catalogued as rs1170701318; called by muse, mutect2, varscan2
- SLC17A6 | c.424G>A p.G142R | Missense Mutation (SNP) | VAF 162/411 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1229947748; called by muse, mutect2, varscan2
- SLC22A10 | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 242/334 reads (72%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); catalogued as rs767537346; called by muse, mutect2, varscan2
- SLC22A25 | c.1124G>A p.G375E | Missense Mutation (SNP) | VAF 178/262 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs267603086, COSV60597007; called by muse, mutect2, varscan2
- SLC22A8 | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 139/195 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1402062009, COSV100267944; called by muse, mutect2, varscan2
- SLC38A1 | c.1126C>T p.R376C | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs760301822, COSV67063091, COSV67064262; called by muse, mutect2, varscan2
- SLC38A9 | c.97G>A p.D33N | Missense Mutation (SNP) | VAF 121/309 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs549527585; called by muse, mutect2, varscan2
- SLC44A5 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 260/482 reads (54%) | SIFT tolerated (0.85); PolyPhen benign (0.216); catalogued as COSV63759539, COSV63760252; called by muse, varscan2
- SLC45A4 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 189/717 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1406784047; called by muse, mutect2, varscan2
- SLC4A10 | c.1177A>G p.T393A (on ENST00000446997 / NM_001354461.2; = p.T363A on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 128/341 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1480765679; called by muse, mutect2, varscan2
- SLC5A1 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 92/262 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs752307170, COSV99833655; called by muse, mutect2, varscan2
- SLC5A8 | c.1376G>A p.G459E | Missense Mutation (SNP) | VAF 200/455 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101610530; called by muse, mutect2, varscan2
- SLC7A3 | c.1111C>T p.R371C | Missense Mutation (SNP) | VAF 210/484 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.932); catalogued as rs1380220296, COSV99979817; called by muse, mutect2, varscan2
- SLC9A6 | c.520C>T p.R174* | Nonsense Mutation (SNP) | VAF 201/384 reads (52%) | catalogued as COSV65787995; called by muse, mutect2, varscan2
- SLC9C2 | c.920C>T p.S307L | Missense Mutation (SNP) | VAF 107/159 reads (67%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as rs1277971580, COSV62945459; called by muse, mutect2, varscan2
- SLCO1A2 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 105/289 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56598935, COSV56605393; called by muse, mutect2, varscan2
- SLCO6A1 | c.668C>T p.S223L | Missense Mutation (SNP) | VAF 174/457 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.082); catalogued as COSV65809232; called by muse, mutect2, varscan2
- SLFN12L | c.1644C>G p.I548M (on ENST00000260908 / NM_001363830.1; = p.I566M on NM_001195790.1) | Missense Mutation (SNP) | VAF 181/410 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.162); catalogued as COSV99610201; called by muse, mutect2, varscan2
- SLFN14 | c.490G>A p.V164M | Missense Mutation (SNP) | VAF 162/612 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs773940313; called by muse, mutect2, varscan2
- SLITRK2 | c.305G>A p.R102Q | Missense Mutation (SNP) | VAF 428/834 reads (51%) | SIFT tolerated (0.62); PolyPhen benign (0.084); catalogued as rs1451408651, COSV59424099; called by muse, mutect2, varscan2
- SLITRK4 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 250/725 reads (34%) | SIFT tolerated (0.64); PolyPhen possibly damaging (0.564); catalogued as COSV100567282; called by muse, mutect2, varscan2
- SMARCA1 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 156/321 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs964072317, COSV64411036; called by muse, mutect2, varscan2
- SNAP91 | c.430G>A p.D144N | Missense Mutation (SNP) | VAF 135/328 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1404151187; called by muse, mutect2, varscan2
- SNAPC1 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 115/376 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.185); catalogued as COSV53520434; called by muse, mutect2, varscan2
- SON | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 217/606 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.736); catalogued as rs779585403; called by muse, mutect2, varscan2
- SORCS3 | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 144/227 reads (63%) | SIFT tolerated (0.92); PolyPhen benign (0.003); catalogued as COSV63828741; called by muse, mutect2, varscan2
- SPANXN3 | c.179G>A p.G60D | Missense Mutation (SNP) | VAF 299/526 reads (57%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.856); catalogued as COSV65140886; called by muse, mutect2, varscan2
- SPEF2 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 278/482 reads (58%) | catalogued as rs899298808, COSV99214331; called by muse, mutect2, varscan2
- SPEG | c.8273C>T p.P2758L | Missense Mutation (SNP) | VAF 206/514 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs745655345; called by muse, mutect2, varscan2
- SPIRE2 | c.808C>T p.L270F | Missense Mutation (SNP) | VAF 211/321 reads (66%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs1362959934; called by muse, mutect2, varscan2
- SPN | c.934G>A p.E312K | Missense Mutation (SNP) | VAF 208/518 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64070090; called by muse, mutect2, varscan2
- SPRR3 | c.424C>T p.P142S | Missense Mutation (SNP) | VAF 671/926 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as COSV54879165; called by muse, varscan2
- SPTA1 | c.4928G>A p.G1643E | Missense Mutation (SNP) | VAF 183/914 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs369900804; called by muse, mutect2, varscan2
- SPTA1 | c.2690C>T p.A897V | Missense Mutation (SNP) | VAF 228/1222 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV63760268; called by muse, mutect2, varscan2
- SSTR1 | c.409G>A p.D137N | Missense Mutation (SNP) | VAF 206/476 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs546561451, COSV57456788; called by muse, mutect2, varscan2
- ST6GALNAC2 | c.434C>T p.P145L | Missense Mutation (SNP) | VAF 189/512 reads (37%) | PolyPhen benign (0.01); catalogued as rs768307376; called by muse, mutect2, varscan2
- ST8SIA2 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 208/515 reads (40%) | PolyPhen probably damaging (0.992); catalogued as COSV51569144; called by muse, mutect2, varscan2
- SULT2B1 | c.716C>T p.S239F (on ENST00000201586 / NM_177973.2; = p.S224F on NM_004605.2) | Missense Mutation (SNP) | VAF 215/547 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1407815723, COSV99572120; called by muse, mutect2, varscan2
- SUSD2 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 182/859 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.119); catalogued as rs781209561; called by muse, mutect2
- SVEP1 | c.5441C>T p.S1814L | Missense Mutation (SNP) | VAF 196/501 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.863); catalogued as rs571724898, COSV52837977; called by muse, mutect2, varscan2
- SYNE3 | c.874C>T p.P292S | Missense Mutation (SNP) | VAF 386/686 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62081291; called by muse, mutect2, varscan2
- TAF11L14 | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 120/332 reads (36%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.777); catalogued as rs1257547941; called by muse, mutect2, varscan2
- TAS2R7 | c.374G>A p.R125K | Missense Mutation (SNP) | VAF 211/537 reads (39%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.889); catalogued as rs759400853; called by muse, mutect2, varscan2
- TAT | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 107/266 reads (40%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV63533099; called by muse, mutect2, varscan2
- TBC1D30 | c.2146C>T p.P716S (on ENST00000542120; = p.P553S on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 184/454 reads (41%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.007); catalogued as rs1321697379, COSV57481072; called by muse, mutect2, varscan2
- TBC1D8 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 125/180 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as rs775313531, COSV65212274, COSV65215055; called by muse, mutect2, varscan2
- TBL1X | c.218C>T p.S73F | Missense Mutation (SNP) | VAF 128/348 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.071); catalogued as COSV54276931; called by muse, mutect2, varscan2
- TENM4 | c.5150G>A p.R1717Q | Missense Mutation (SNP) | VAF 185/1011 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); catalogued as rs761735333, COSV53662569; called by muse, mutect2, varscan2
- TENM4 | c.3241C>T p.H1081Y | Missense Mutation (SNP) | VAF 199/1263 reads (16%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs1234905744; called by muse, mutect2, varscan2
- TET3 | c.2002G>A p.A668T | Missense Mutation (SNP) | VAF 253/1038 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.279); catalogued as rs1474299176; called by muse, mutect2, varscan2
- TEX11 | c.1809G>A p.M603I (on ENST00000344304; = p.M588I on NM_031276.3) | Missense Mutation (SNP) | VAF 126/359 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as COSV60228467; called by muse, mutect2, varscan2
- TEX13C | c.283G>A p.G95R | Missense Mutation (SNP) | VAF 250/543 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.264); catalogued as rs1394802337; called by muse, mutect2, varscan2
- TFAP2A | c.60C>A p.H20Q (on ENST00000482890; = p.H12Q on NM_001032280.3) | Missense Mutation (SNP) | VAF 247/450 reads (55%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.968); catalogued as COSV100117304; called by muse, mutect2, varscan2
- TFAP2B | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 194/355 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99540504; called by muse, mutect2, varscan2
- TFEC | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 91/290 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55405319; called by muse, mutect2, varscan2
- TFF1 | c.190G>A p.G64R | Missense Mutation (SNP) | VAF 162/463 reads (35%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV52298283; called by muse, mutect2, varscan2
- TFIP11 | c.1943C>T p.S648F | Missense Mutation (SNP) | VAF 190/503 reads (38%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.996); catalogued as rs758124053; called by muse, mutect2, varscan2
- THOC2 | c.3112C>T p.R1038* | Nonsense Mutation (SNP) | VAF 138/374 reads (37%) | catalogued as COSV55550674; called by muse, mutect2, varscan2
- THOP1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 193/448 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.339); catalogued as rs1393881161; called by muse, mutect2, varscan2
- THSD7A | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 162/238 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1051817932, COSV70264321; called by muse, mutect2, varscan2
- THSD7B | c.968C>T p.S323F | Missense Mutation (SNP) | VAF 76/226 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.851); catalogued as rs267598895, COSV55707231; called by muse, mutect2, varscan2
- THSD7B | c.3067C>T p.R1023* | Nonsense Mutation (SNP) | VAF 188/460 reads (41%) | catalogued as rs750153977, COSV55661886; called by muse, mutect2, varscan2
- TIAM2 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 140/225 reads (62%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.999); catalogued as COSV59689620; called by muse, mutect2, varscan2
- TMEM132B | c.2348G>A p.G783E | Missense Mutation (SNP) | VAF 133/358 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54754134; called by muse, mutect2, varscan2
- TMEM132D | c.1334G>A p.G445E | Missense Mutation (SNP) | VAF 168/453 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101397341; called by muse, mutect2, varscan2
- TMEM156 | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 104/277 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.214); catalogued as rs775330615, COSV100756073; called by muse, mutect2, varscan2
- TMEM196 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 126/171 reads (74%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.81); catalogued as rs772975014; called by muse, mutect2, varscan2
- TMEM222 | c.17G>T p.G6V | Missense Mutation (SNP) | VAF 200/433 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.189); catalogued as COSV65027003; called by muse, mutect2, varscan2
- TMEM30A | c.968C>T p.P323L | Missense Mutation (SNP) | VAF 173/423 reads (41%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); catalogued as COSV100035024, COSV57876591; called by muse, mutect2, varscan2
- TMEM37 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 196/451 reads (43%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.526); catalogued as COSV50030631; called by muse, mutect2, varscan2
- TMEM40 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 153/431 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs766488618; called by muse, mutect2, varscan2
- TMEM47 | c.488C>T p.S163L | Missense Mutation (SNP) | VAF 216/530 reads (41%) | SIFT tolerated (0.17); PolyPhen benign (0.272); catalogued as rs267606443, COSV52066095; called by muse, mutect2, varscan2
- TMEM63C | c.1303G>A p.D435N | Missense Mutation (SNP) | VAF 359/656 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.595); catalogued as rs753419467; called by muse, mutect2, varscan2
- TMEM87B | c.1322C>T p.S441L | Missense Mutation (SNP) | VAF 144/384 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as rs769088454, COSV51718572; called by muse, mutect2, varscan2
- TNFRSF10C | c.103C>T p.P35S | Missense Mutation (SNP) | VAF 126/398 reads (32%) | SIFT tolerated, low confidence (0.43); PolyPhen possibly damaging (0.878); catalogued as COSV63511484; called by muse, mutect2, varscan2
- TNFRSF8 | c.1099C>T p.P367S | Missense Mutation (SNP) | VAF 395/660 reads (60%) | SIFT tolerated (0.89); PolyPhen benign (0.003); catalogued as rs1280237725, COSV55795723; called by muse, mutect2, varscan2
- TNNT2 | c.488C>T p.A163V | Missense Mutation (SNP) | VAF 128/187 reads (68%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); catalogued as rs1244759400, CM1412269, COSV52663547; called by muse, mutect2, varscan2
- TNXB | c.6850G>A p.E2284K (on ENST00000647633; = p.E2037K on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/729 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.181); catalogued as rs771629431; called by muse, mutect2, varscan2
- TNXB | c.2369C>T p.A790V | Missense Mutation (SNP) | VAF 223/383 reads (58%) | SIFT tolerated (0.73); PolyPhen benign (0.021); catalogued as rs1321595318, COSV64472461; called by muse, mutect2, varscan2
- TOPAZ1 | c.2045G>A p.G682E | Missense Mutation (SNP) | VAF 149/366 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs1226850089; called by muse, mutect2, varscan2
- TPM4 | c.137C>T p.T46I (on ENST00000300933; = p.N53= on NM_003290.3) | Missense Mutation (SNP) | VAF 142/326 reads (44%) | catalogued as COSV99959219; called by muse, mutect2, varscan2
- TRAF3IP3 | c.652C>T p.L218F | Missense Mutation (SNP) | VAF 200/283 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV50553473; called by muse, mutect2, varscan2
- TRANK1 | c.6133G>A p.E2045K | Missense Mutation (SNP) | VAF 159/396 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs866209162, COSV57145250; called by muse, mutect2, varscan2
- TRHR | c.971C>T p.S324F | Missense Mutation (SNP) | VAF 193/466 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1411216110; called by muse, mutect2, varscan2
- TRIM55 | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 278/501 reads (55%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.772); catalogued as rs267601968, COSV52552279; called by muse, mutect2, varscan2
- TRIM61 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 94/258 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.928); catalogued as COSV100256104; called by muse, mutect2
- TRIOBP | c.6152A>T p.N2051I (on ENST00000644935 / NM_001039141.3; = p.N338I on NM_007032.5) | Missense Mutation (SNP) | VAF 255/627 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.174); catalogued as rs1221832842; called by muse, mutect2, varscan2
- TRIP13 | c.191C>T p.P64L | Missense Mutation (SNP) | VAF 333/407 reads (82%) | SIFT tolerated (0.28); PolyPhen benign (0.037); catalogued as rs956213254; called by muse, mutect2, varscan2
- TRPC6 | c.1951G>A p.G651R | Missense Mutation (SNP) | VAF 166/235 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60252470; called by muse, mutect2, varscan2
- TRRAP | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 123/316 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100721802; called by muse, mutect2, varscan2
- TSPYL5 | c.970C>T p.R324C | Missense Mutation (SNP) | VAF 212/764 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.892); catalogued as rs867103164, COSV100438937, COSV100439118; called by muse, mutect2, varscan2
- TTLL6 | c.1361G>A p.R454Q (on ENST00000393382 / NM_001130918.3; = p.R147Q on NM_173623.3) | Missense Mutation (SNP) | VAF 146/364 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs776686296, COSV100938135; called by muse, mutect2, varscan2
- TTN | c.78043G>A p.E26015K (on ENST00000591111; = p.E18591K on NM_003319.4) | Missense Mutation (SNP) | VAF 113/290 reads (39%) | PolyPhen benign (0.043); catalogued as rs1001344341; called by muse, mutect2, varscan2
- TTN | c.38375G>A p.R12792K (on ENST00000591111; = p.R5368K on NM_003319.4) | Missense Mutation (SNP) | VAF 159/453 reads (35%) | PolyPhen probably damaging (0.987); catalogued as rs914023000; called by muse, mutect2, varscan2
- TTN | c.35614G>A p.E11872K (on ENST00000591111; = p.E4448K on NM_003319.4) | Missense Mutation (SNP) | VAF 95/254 reads (37%) | PolyPhen probably damaging (0.987); catalogued as COSV59952825; called by muse, mutect2, varscan2
- TTN | c.18170G>A p.R6057K (on ENST00000591111; = p.R5130K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 132/364 reads (36%) | PolyPhen benign (0); catalogued as COSV59950329; called by muse, mutect2, varscan2
- TTN | c.11437G>A p.E3813K (on ENST00000591111; = p.E3767K on NM_003319.4) | Missense Mutation (SNP) | VAF 193/475 reads (41%) | catalogued as COSV59894244; called by muse, mutect2, varscan2
- TUBGCP6 | c.3620C>T p.P1207L | Missense Mutation (SNP) | VAF 172/459 reads (37%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs558422866; called by muse, mutect2, varscan2
- UBN1 | c.396T>G p.Y132* | Nonsense Mutation (SNP) | VAF 114/323 reads (35%) | catalogued as COSV99277654; called by muse, mutect2, varscan2
- UGT1A8 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 150/374 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769499369; called by muse, mutect2, varscan2
- UGT2A2 | c.362G>A p.G121E | Missense Mutation (SNP) | VAF 156/354 reads (44%) | SIFT tolerated (0.8); PolyPhen benign (0.231); catalogued as COSV54138004; called by muse, mutect2, varscan2
- UGT3A1 | c.539C>A p.P180H | Missense Mutation (SNP) | VAF 197/786 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57100335; called by muse, mutect2, varscan2
- UHRF1BP1 | c.2197C>T p.R733C | Missense Mutation (SNP) | VAF 216/744 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs1025338905, COSV51957315; called by muse, mutect2, varscan2
- UNC79 | c.2534G>A p.G845E (on ENST00000393151 / NM_001346218.2; = p.G668E on NM_020818.5) | Missense Mutation (SNP) | VAF 440/771 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs765969402, COSV56376159, COSV56386310, COSV56392104; called by muse, mutect2, varscan2
- UNC79 | c.4067G>A p.G1356E (on ENST00000393151 / NM_001346218.2; = p.G1179E on NM_020818.5) | Missense Mutation (SNP) | VAF 153/590 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56391650, COSV56392180; called by muse, mutect2, varscan2
- UNC79 | c.6823C>T p.P2275S (on ENST00000393151 / NM_001346218.2; = p.P2098S on NM_020818.5) | Missense Mutation (SNP) | VAF 342/594 reads (58%) | SIFT tolerated (0.45); PolyPhen benign (0.197); catalogued as COSV56378041; called by muse, mutect2, varscan2
- UNC79 | c.7639G>A p.E2547K (on ENST00000393151 / NM_001346218.2; = p.E2370K on NM_020818.5) | Missense Mutation (SNP) | VAF 361/634 reads (57%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as COSV56379059; called by muse, mutect2, varscan2
- UNC80 | c.1222G>A p.E408K | Missense Mutation (SNP) | VAF 114/307 reads (37%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.97); catalogued as rs758895481, COSV55901070; called by muse, mutect2, varscan2
- UNCX | c.238G>A p.G80R | Missense Mutation (SNP) | VAF 209/505 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.056); catalogued as rs1256683027; called by muse, mutect2, varscan2
- USP17L4 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 232/704 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777909045; called by muse, mutect2
- USP29 | c.727C>T p.L243F | Missense Mutation (SNP) | VAF 145/392 reads (37%) | SIFT tolerated (0.44); PolyPhen benign (0.03); catalogued as COSV54140490; called by muse, mutect2, varscan2
- USP29 | c.2347C>T p.H783Y | Missense Mutation (SNP) | VAF 179/496 reads (36%) | SIFT tolerated (0.36); PolyPhen benign (0.018); catalogued as rs1325936474; called by muse, mutect2, varscan2
- USP32 | c.3322C>T p.P1108S | Missense Mutation (SNP) | VAF 218/536 reads (41%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.539); catalogued as COSV100342947; called by muse, mutect2, varscan2
- USP4 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 104/312 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.021); catalogued as rs961769016; called by muse, mutect2, varscan2
- USP4 | c.758C>T p.S253F | Missense Mutation (SNP) | VAF 148/385 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.157); catalogued as COSV55540528; called by muse, mutect2, varscan2
- VAV1 | c.2173G>A p.G725R | Missense Mutation (SNP) | VAF 150/443 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267605754, COSV58393927; called by muse, mutect2, varscan2
- VGLL4 | c.595C>T p.P199S | Missense Mutation (SNP) | VAF 154/419 reads (37%) | SIFT tolerated (0.9); PolyPhen benign (0.02); catalogued as COSV56076401; called by muse, mutect2, varscan2
- VIM | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 134/201 reads (67%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs1200409133; called by muse, mutect2, varscan2
- VIPR1 | c.80G>A p.G27D | Missense Mutation (SNP) | VAF 119/300 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.014); catalogued as rs866308427; called by muse, mutect2, varscan2
- VWA3A | c.3506C>T p.S1169F | Missense Mutation (SNP) | VAF 160/442 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs1434955003, COSV55388337; called by muse, mutect2, varscan2
- VWA3B | c.3421G>A p.E1141K | Missense Mutation (SNP) | VAF 88/325 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.815); catalogued as COSV101417789; called by muse, mutect2, varscan2
- WASHC2A | c.3740C>T p.P1247L | Missense Mutation (SNP) | VAF 51/107 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as rs1359641143; called by muse, varscan2
- WDHD1 | c.2678C>T p.S893F | Missense Mutation (SNP) | VAF 85/245 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs1238435703; called by muse, mutect2, varscan2
- WDR33 | c.3104G>A p.R1035Q | Missense Mutation (SNP) | VAF 220/547 reads (40%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.885); catalogued as rs746356662; called by muse, mutect2, varscan2
- WDSUB1 | c.212C>T p.S71L | Missense Mutation (SNP) | VAF 175/490 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1274167227; called by muse, varscan2
- WFDC8 | c.155C>T p.P52L | Missense Mutation (SNP) | VAF 155/824 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.591); catalogued as COSV51489681; called by muse, mutect2, varscan2
- WHRN | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 126/300 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.012); catalogued as rs1287032253; called by muse, mutect2, varscan2
1,662 further variants in this file (803 protein-altering or splice-affecting, 771 silent, 88 other) are not listed here.
